Somatic mutation profile of tumor specimen TCGA-D3-A2JF-06A (aliquot TCGA-D3-A2JF-06A-11D-A196-08) from TCGA case TCGA-D3-A2JF, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 76.1 years (27,799 days).
Specimen TCGA-D3-A2JF-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 83d18fa6-c8b6-4b05-8e56-861936438492.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D3-A2JF-10A (Blood Derived Normal), aliquot TCGA-D3-A2JF-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/478faadb-2872-414a-a482-d2d8ea7c193a

The open-access MAF lists 1,732 somatic variants for this specimen: 1,150 protein-altering or splice-affecting, 536 silent, 46 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,041, Silent 536, Nonsense Mutation 83, Intron 20, RNA 14, Splice Site 10, Splice Region 9, 5'Flank 6, Frame Shift Del 3, 5'UTR 3, Translation Start Site 2, 3'UTR 2.

Variants (750 of 1,732; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 80/132 reads (61%) | hotspot (GDC flag); catalogued as rs121913388, CM014695, COSV58682746, COSV58721651; ClinVar: risk factor / likely pathogenic; called by muse, mutect2, varscan2
- CFTR | c.3718-1G>A p.X1240_splice | Splice Site (SNP) | VAF 18/66 reads (27%) | catalogued as rs387906369, CS930772, COSV50041575; ClinVar: pathogenic; called by muse, varscan2
- HRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 33/73 reads (45%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.251); catalogued as rs104894226, CM053285, COSV54237021, COSV54237051; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- IL7R | c.616C>T p.R206* | Nonsense Mutation (SNP) | VAF 20/54 reads (37%) | hotspot (GDC flag); catalogued as rs201559094, CM045175, COSV57405649; called by muse, mutect2, varscan2
- KCNJ8 | c.1250G>A p.G417E | Missense Mutation (SNP) | VAF 52/103 reads (50%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.131); catalogued as COSV53715303; called by muse, mutect2, varscan2
- SCN5A | c.4217G>A p.G1406E (on ENST00000333535 / NM_198056.3; = p.G1405E on NM_000335.5) | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs199473609, CM100716, COSV100346805; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.356G>A p.G119E | Missense Mutation (SNP) | VAF 30/133 reads (23%) | SIFT tolerated (0.84); PolyPhen benign (0.007); catalogued as COSV55286134; called by muse, mutect2, varscan2
- AAK1 | c.2522C>T p.P841L | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.026); catalogued as COSV101275871; called by muse, mutect2
- ABCA1 | c.2438C>T p.P813L | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV66063991, COSV66071356; called by muse, mutect2, varscan2
- ABCA13 | c.2494C>T p.P832S | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0.199); catalogued as COSV70026006; called by muse, mutect2, varscan2
- ABCA2 | c.3569G>A p.R1190H (on ENST00000614293; = p.R1160H on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377033370; called by muse, mutect2, varscan2
- ABCA4 | c.3808G>A p.E1270K | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as CM003378, COSV64671224; called by muse, mutect2, varscan2
- ABCB4 | c.731A>G p.K244R | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.084); catalogued as COSV55932328; called by muse, mutect2, varscan2
- ABCC8 | c.664G>C p.V222L | Missense Mutation (SNP) | VAF 275/953 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as CM118599, COSV56846669, COSV56847939, COSV56857898; called by muse, mutect2, varscan2
- ABCG8 | c.949C>T p.P317S | Missense Mutation (SNP) | VAF 80/342 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as rs762542767, COSV55390931; called by muse, mutect2, varscan2
- ABL2 | c.2903C>T p.S968F (on ENST00000502732 / NM_007314.4; = p.S953F on NM_005158.5) | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.365); catalogued as rs774754926, COSV61011263; called by muse, mutect2, varscan2
- ABLIM3 | c.405G>C p.Q135H | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV58639584; called by muse, mutect2, varscan2
- AC005833.1 | c.1004C>T p.S335F | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0.01); catalogued as rs750919954, COSV52894841; called by muse, mutect2, varscan2
- ACKR1 | c.34C>T p.P12S | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.59); PolyPhen benign (0.019); catalogued as COSV100929489, COSV100929714; called by muse, mutect2, varscan2
- ACKR1 | c.35C>T p.P12L | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.72); PolyPhen benign (0.006); catalogued as COSV100929492; called by muse, mutect2, varscan2
- ACOT11 | c.1766T>C p.L589P | Missense Mutation (SNP) | VAF 12/21 reads (57%) | catalogued as COSV64893357; called by muse, mutect2, varscan2
- ACOT6 | c.460C>T p.P154S | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs867873268, COSV66968794; called by muse, mutect2, varscan2
- ACOXL | c.500G>A p.G167E | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.072); catalogued as COSV61322133; called by muse, mutect2, varscan2
- ACSL6 | c.1663C>T p.R555W (on ENST00000379240; = p.R580W on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs906232409, COSV57294622, COSV57299238; called by muse, mutect2, varscan2
- ACSM2B | c.388G>A p.G130S | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61656874, COSV61656909; called by muse, mutect2, varscan2
- ADAM19 | c.304C>T p.P102S | Missense Mutation (SNP) | VAF 52/144 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.021); catalogued as COSV57423319, COSV57430681; called by muse, mutect2, varscan2
- ADAMTS12 | c.3137C>T p.P1046L | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV61256141; called by muse, mutect2, varscan2
- ADAMTS13 | c.2999G>A p.R1000H | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); catalogued as rs781905328, COSV63020047; called by muse, mutect2, varscan2
- ADAMTS18 | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 41/73 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV51418182; called by muse, mutect2, varscan2
- ADAMTS2 | c.2794C>T p.R932W | Missense Mutation (SNP) | VAF 71/164 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as rs776975672, COSV52365349, COSV52372006; called by muse, mutect2, varscan2
- ADAMTS20 | c.749G>A p.R250K | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101240364, COSV67126686; called by muse, mutect2, varscan2
- ADAMTS6 | c.2903G>A p.W968* | Nonsense Mutation (SNP) | VAF 40/127 reads (31%) | catalogued as COSV58681646; called by muse, mutect2, varscan2
- ADAMTS7 | c.4734G>A p.W1578* | Nonsense Mutation (SNP) | VAF 15/27 reads (56%) | catalogued as COSV66305932; called by muse, mutect2, varscan2
- ADAMTS8 | c.1546G>A p.E516K | Missense Mutation (SNP) | VAF 36/66 reads (55%) | SIFT tolerated (0.49); PolyPhen benign (0.108); catalogued as COSV99960456; called by muse, mutect2, varscan2
- ADCY5 | c.2027C>T p.A676V | Missense Mutation (SNP) | VAF 62/172 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as COSV59194505; called by muse, mutect2, varscan2
- ADCY8 | c.1004G>A p.G335E | Missense Mutation (SNP) | VAF 62/192 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867747553, COSV53897387; called by muse, mutect2, varscan2
- ADGRF1 | c.1774G>A p.G592R | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51944086; called by muse, mutect2, varscan2
- ADGRL2 | c.680G>A p.R227K | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV54653742; called by muse, mutect2, varscan2
- ADGRV1 | c.623C>T p.P208L | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.97); catalogued as COSV67979015; called by muse, mutect2, varscan2
- ADGRV1 | c.5345G>A p.G1782E | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101315626, COSV67979021; called by muse, mutect2, varscan2
- ADGRV1 | c.5716G>A p.D1906N | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.358); catalogued as COSV101315791, COSV67979024; called by muse, mutect2, varscan2
- ADGRV1 | c.7805C>T p.P2602L | Missense Mutation (SNP) | VAF 110/272 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as COSV67979026; called by muse, mutect2, varscan2
- AFAP1L1 | c.394C>T p.P132S | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99695657; called by muse, mutect2, varscan2
- AFAP1L1 | c.395C>T p.P132L | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99695658; called by muse, mutect2, varscan2
- AGBL2 | c.1963G>A p.G655S | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs550681817, COSV54090172; called by muse, mutect2
- AGT | c.1190C>T p.A397V | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.329); catalogued as COSV64183922; called by muse, mutect2, varscan2
- AHCYL1 | c.127C>T p.Q43* | Nonsense Mutation (SNP) | VAF 19/46 reads (41%) | catalogued as COSV63208238; called by muse, mutect2, varscan2
- AHNAK2 | c.12739G>T p.G4247C | Missense Mutation (SNP) | VAF 39/188 reads (21%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.993); catalogued as COSV60908490; called by muse, mutect2, varscan2
- AIDA | c.325C>T p.P109S | Missense Mutation (SNP) | VAF 30/165 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV60663074; called by muse, mutect2, varscan2
- AK9 | c.2969C>T p.P990L | Missense Mutation (SNP) | VAF 57/102 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1418398139, COSV58137723; called by muse, mutect2, varscan2
- AKR1C8P | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 14/43 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs782008932; called by muse, mutect2
- AL121899.2 | c.1006G>A p.G336R | Missense Mutation (SNP) | VAF 71/213 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1422704240, COSV67349782; called by muse, mutect2, varscan2
- ALDH2 | c.1294G>A p.E432K | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV55665189; called by muse, mutect2, varscan2
- ALDH5A1 | c.1493C>T p.S498F | Missense Mutation (SNP) | VAF 110/221 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.604); catalogued as rs867032162, COSV62372820; called by muse, mutect2, varscan2
- ALDOB | c.544G>A p.G182R | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.918); catalogued as COSV66397291; called by muse, mutect2, varscan2
- ALDOB | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 59/285 reads (21%) | SIFT tolerated (0.85); PolyPhen benign (0.015); catalogued as rs867022678, COSV66397306; called by muse, mutect2, varscan2
- ALOX12B | c.232C>T p.P78S | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.062); catalogued as rs1466188561, COSV59871201; called by muse, mutect2, varscan2
- ALPK3 | c.1764G>A p.M588I | Missense Mutation (SNP) | VAF 44/106 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.117); catalogued as COSV51930150, COSV51932708; called by muse, mutect2, varscan2
- ALPP | c.198G>A p.M66I | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); catalogued as rs773932975, COSV67395673; called by muse, mutect2, varscan2
- AMBRA1 | c.328C>T p.L110F | Missense Mutation (SNP) | VAF 40/127 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV54049046; called by muse, mutect2, varscan2
- ANGEL2 | c.141G>A p.W47* | Nonsense Mutation (SNP) | VAF 45/108 reads (42%) | catalogued as rs757257905, COSV100853988, COSV64736873; called by muse, mutect2, varscan2
- ANGPT1 | c.1406G>A p.G469E | Missense Mutation (SNP) | VAF 55/162 reads (34%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.777); catalogued as COSV52431609, COSV52458601; called by muse, mutect2, varscan2
- ANGPT1 | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.967); catalogued as rs867964520, COSV52431619, COSV99864298; called by muse, mutect2, varscan2
- ANK3 | c.11174G>A p.G3725E | Missense Mutation (SNP) | VAF 92/211 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs866080086, COSV55045285; called by muse, mutect2, varscan2
- ANK3 | c.3680G>A p.G1227E (on ENST00000280772 / NM_001320874.2; = p.G361E on NM_001149.3) | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as rs1445239454, COSV55045306; called by muse, mutect2, varscan2
- ANK3 | c.2902G>A p.D968N (on ENST00000280772 / NM_001320874.2; = p.D102N on NM_001149.3) | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV55045327; called by muse, mutect2, varscan2
- ANKEF1 | c.604C>T p.R202* | Nonsense Mutation (SNP) | VAF 58/150 reads (39%) | catalogued as rs774211930, COSV65691928; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.5422C>T p.P1808S | Missense Mutation (SNP) | VAF 39/118 reads (33%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.005); catalogued as COSV51840969; called by muse, mutect2, varscan2
- ANKLE1 | c.1943C>T p.A648V (on ENST00000394458; = p.A594V on NM_152363.6) | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV66729981; called by muse, mutect2
- ANKRD12 | c.5194C>T p.P1732S | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); catalogued as rs1014443518, COSV100040913, COSV50819304; called by muse, mutect2, varscan2
- ANKRD33 | c.578C>T p.P193L (on ENST00000340970 / NM_001304459.2; = p.P318L on NM_182608.4) | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56605036; called by muse, mutect2, varscan2
- ANO3 | c.2587G>T p.G863* | Nonsense Mutation (SNP) | VAF 24/89 reads (27%) | catalogued as COSV56781463; called by muse, mutect2, varscan2
- ANO4 | c.657G>C p.R219S (on ENST00000392977 / NM_001286615.2; = p.R184S on NM_178826.4) | Missense Mutation (SNP) | VAF 103/229 reads (45%) | SIFT tolerated (0.38); PolyPhen benign (0.013); catalogued as COSV54586391; called by muse, mutect2, varscan2
- APBB1IP | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV66130623, COSV66130669, COSV66130705; called by muse, varscan2
- APCS | c.421G>A p.G141S | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV54817236, COSV54817899; called by muse, mutect2, varscan2
- APOB | c.10682C>T p.S3561F | Missense Mutation (SNP) | VAF 140/660 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as COSV51924363; called by muse, mutect2, varscan2
- APOB | c.9739C>T p.Q3247* | Nonsense Mutation (SNP) | VAF 207/460 reads (45%) | catalogued as COSV51921524, COSV51924376; called by muse, mutect2, varscan2
- APOB | c.9397C>T p.P3133S | Missense Mutation (SNP) | VAF 118/623 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51924392; called by muse, mutect2, varscan2
- APOB | c.5225T>C p.M1742T | Missense Mutation (SNP) | VAF 211/875 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.276); catalogued as rs151035908, COSV51924406; called by muse, mutect2, varscan2
- ARFGEF1 | c.1487C>T p.S496F | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); catalogued as COSV51602977; called by muse, mutect2, varscan2
- ARHGAP1 | c.445C>G p.R149G | Missense Mutation (SNP) | VAF 45/97 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs138044269, COSV61734390; called by muse, mutect2, varscan2
- ARHGAP10 | c.2197G>C p.A733P | Missense Mutation (SNP) | VAF 33/63 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60595246; called by muse, mutect2, varscan2
- ARHGAP12 | c.1061T>C p.L354S | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV60961542; called by muse, mutect2, varscan2
- ARHGAP28 | c.998G>A p.G333E (on ENST00000383472 / NM_001366230.1; = p.G174E on NM_001010000.3) | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.018); catalogued as COSV51631942; called by muse, mutect2, varscan2
- ARHGAP35 | c.1159C>T p.P387S | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.413); catalogued as COSV68329322; called by muse, mutect2, varscan2
- ARHGAP35 | c.4000C>T p.P1334S | Missense Mutation (SNP) | VAF 41/156 reads (26%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.85); catalogued as COSV68329330; called by muse, mutect2, varscan2
- ARHGAP6 | c.1127G>A p.R376Q | Missense Mutation (SNP) | VAF 75/115 reads (65%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.59); catalogued as COSV57291586; called by muse, mutect2, varscan2
- ARHGEF11 | c.841C>T p.Q281* | Nonsense Mutation (SNP) | VAF 12/58 reads (21%) | catalogued as COSV63810508; called by muse, mutect2, varscan2
- ARID2 | c.2128C>T p.P710S | Missense Mutation (SNP) | VAF 58/131 reads (44%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0); catalogued as COSV57596580; called by muse, mutect2, varscan2
- ARID4A | c.38G>A p.G13E | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62162101; called by muse, mutect2, varscan2
- ARL16 | c.31C>T p.R11C | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV100230284; called by muse, varscan2
- ARMH4 | c.406C>T p.P136S | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.271); catalogued as rs1420793410, COSV50761822; called by muse, mutect2, varscan2
- ARNTL | c.826C>T p.R276* (on ENST00000403290 / NM_001297719.2; = p.R275* on NM_001178.5 and 4 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 48/195 reads (25%) | catalogued as COSV62985315; called by muse, mutect2, varscan2
- ARSK | c.320C>T p.P107L | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.076); catalogued as rs756938553, COSV66169277; called by muse, mutect2, varscan2
- ASCC3 | c.304C>T p.H102Y | Missense Mutation (SNP) | VAF 22/28 reads (79%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs747446652, COSV61225941, COSV61235818; called by muse, mutect2, varscan2
- ASGR2 | c.919A>C p.T307P | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs762570355, COSV54689334; called by muse, mutect2, varscan2
- ASMTL | c.392C>T p.S131F | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.71); PolyPhen benign (0.4); catalogued as COSV67242961; called by muse, mutect2, varscan2
- ASTN1 | c.1133G>A p.R378Q | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.021); catalogued as rs760442147, COSV56061330; called by muse, mutect2, varscan2
- ASZ1 | c.179C>T p.S60L | Missense Mutation (SNP) | VAF 41/171 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as COSV52911316; called by muse, mutect2, varscan2
- ATF5 | c.767C>T p.S256F | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61310979; called by muse, mutect2, varscan2
- ATP1B4 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as COSV54311354; called by muse, mutect2, varscan2
- ATP2B4 | c.3307C>T p.Q1103* | Nonsense Mutation (SNP) | VAF 26/80 reads (33%) | catalogued as COSV100396984, COSV58174583; called by muse, mutect2, varscan2
- ATP9A | c.2981C>T p.S994F | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58763465; called by muse, mutect2, varscan2
- AXL | c.2452G>A p.E818K (on ENST00000301178 / NM_021913.5; = p.E809K on NM_001699.6) | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs763066660, COSV56564019; called by muse, mutect2, varscan2
- BARX2 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); catalogued as COSV55649391; called by muse, mutect2, varscan2
- BBOX1 | c.98G>A p.W33* | Nonsense Mutation (SNP) | VAF 19/70 reads (27%) | catalogued as rs751858108, COSV54189351; called by muse, mutect2, varscan2
- BCL7A | c.293C>T p.S98F | Missense Mutation (SNP) | VAF 55/135 reads (41%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.996); catalogued as rs1156239345, COSV55846655; called by muse, mutect2, varscan2
- BFSP1 | c.1099C>T p.P367S | Missense Mutation (SNP) | VAF 49/151 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.231); catalogued as COSV64899427; called by muse, mutect2, varscan2
- BNC2 | c.1741G>A p.E581K | Missense Mutation (SNP) | VAF 52/90 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.108); catalogued as COSV66141034; called by muse, mutect2, varscan2
- BPIFB3 | c.641G>A p.G214E | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as rs1270460136, COSV64956839; called by muse, mutect2, varscan2
- BRDT | c.544C>T p.P182S | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV62863175; called by muse, mutect2, varscan2
- BRINP1 | c.1889G>A p.R630Q | Missense Mutation (SNP) | VAF 81/191 reads (42%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.456); catalogued as rs151087333, COSV56292314; called by muse, mutect2, varscan2
- BRINP2 | c.1297C>T p.P433S | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (0.4); PolyPhen benign (0.142); catalogued as COSV64175547; called by muse, mutect2, varscan2
- BRINP3 | c.595C>T p.Q199* | Nonsense Mutation (SNP) | VAF 14/50 reads (28%) | catalogued as COSV66514373; called by muse, mutect2, varscan2
- BRINP3 | c.11G>A p.R4Q | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as rs367647063, COSV66531909; called by muse, mutect2, varscan2
- BTK | c.539C>T p.S180F | Missense Mutation (SNP) | VAF 43/60 reads (72%) | SIFT tolerated (0.08); PolyPhen benign (0.269); catalogued as COSV58117561, COSV58118994; called by muse, mutect2, varscan2
- BTNL3 | c.1396G>A p.G466R | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV61564399; called by muse, mutect2
- C10orf71 | c.884G>A p.G295E | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60504756; called by muse, mutect2, varscan2
- C12orf43 | c.13A>G p.S5G | Missense Mutation (SNP) | VAF 73/319 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs200002180; called by muse, mutect2, varscan2
- C1QTNF9 | c.554G>A p.G185E | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100129803; called by muse, mutect2, varscan2
- C1QTNF9 | c.935A>C p.N312T | Missense Mutation (SNP) | VAF 45/121 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV59656463; called by muse, mutect2, varscan2
- C1QTNF9B | c.554G>A p.G185E | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65943804; called by mutect2, varscan2
- C1orf210 | c.176G>A p.R59Q | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs374573587; called by muse, mutect2, varscan2
- C20orf194 | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 60/173 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV52691818, COSV52693445; called by muse, mutect2, varscan2
- C3orf20 | c.2231C>T p.S744F | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53782619; called by muse, mutect2, varscan2
- C6 | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs267600638, COSV54704649; called by muse, mutect2, varscan2
- CA11 | c.869C>T p.P290L | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50032745; called by muse, mutect2, varscan2
- CABP5 | c.398C>T p.A133V | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.299); catalogued as COSV53152030, COSV53153948; called by muse, mutect2, varscan2
- CACNA1G | c.5807C>T p.S1936F | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV61720558; called by muse, mutect2, varscan2
- CACNA1S | c.3307C>T p.P1103S | Missense Mutation (SNP) | VAF 46/230 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62936445; called by muse, mutect2, varscan2
- CACNB4 | c.250C>T p.Q84* | Nonsense Mutation (SNP) | VAF 33/78 reads (42%) | catalogued as COSV52389398; called by muse, mutect2, varscan2
- CADM2 | c.718G>A p.E240K (on ENST00000407528 / NM_001167674.2; = p.E242K on NM_153184.4) | Missense Mutation (SNP) | VAF 51/182 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67358651; called by muse, mutect2, varscan2
- CADM2 | c.1151C>T p.S384F (on ENST00000407528 / NM_001167674.2; = p.S386F on NM_153184.4) | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs762997390, COSV101053175, COSV67358658; called by muse, mutect2, varscan2
- CADPS | c.4048G>A p.E1350K | Missense Mutation (SNP) | VAF 56/151 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.107); catalogued as rs147103435, COSV51901025; called by muse, mutect2, varscan2
- CAND1 | c.2699C>G p.T900S | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1309660903, COSV73389535; called by muse, mutect2, varscan2
- CAPN13 | c.1213C>T p.P405S | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV54428562; called by muse, mutect2
- CAPN6 | c.1456A>G p.I486V | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1436181484, COSV60693972; called by muse, mutect2, varscan2
- CAPRIN1 | c.1580C>T p.P527L | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV58218286; called by muse, mutect2, varscan2
- CARD10 | c.2254C>T p.P752S | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.172); catalogued as COSV52654477; called by muse, mutect2, varscan2
- CARMIL1 | c.3009C>T p.V1003= | Splice Region (SNP) | VAF 23/76 reads (30%) | catalogued as COSV100277458, COSV61514000; called by muse, mutect2, varscan2
- CASR | c.591G>A p.M197I | Missense Mutation (SNP) | VAF 55/166 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.054); catalogued as COSV56134477; called by muse, mutect2, varscan2
- CASR | c.1793G>A p.W598* (on ENST00000490131; = p.W675* on NM_000388.4) | Nonsense Mutation (SNP) | VAF 47/145 reads (32%) | catalogued as CM165754, COSV56134489; called by muse, mutect2, varscan2
- CASZ1 | c.2348C>T p.S783L | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.085); catalogued as COSV59732416; called by muse, mutect2, varscan2
- CATSPERB | c.463C>T p.R155* | Nonsense Mutation (SNP) | VAF 15/55 reads (27%) | catalogued as rs779893104, COSV56422429, COSV99831126; called by muse, mutect2, varscan2
- CCDC141 | c.2884G>A p.E962K | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.662); catalogued as COSV55369318; called by muse, mutect2
- CCDC141 | c.2245G>A p.E749K | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.238); catalogued as COSV55369334; called by muse, mutect2, varscan2
- CCDC180 | c.3085G>A p.E1029K | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); catalogued as COSV63827121; called by muse, mutect2, varscan2
- CCDC38 | c.319A>T p.R107W | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV60182272; called by muse, mutect2, varscan2
- CCDC40 | c.1498G>A p.A500T | Missense Mutation (SNP) | VAF 44/107 reads (41%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as rs986794430, COSV53896966; called by muse, mutect2, varscan2
- CCR2 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 42/141 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.055); catalogued as COSV52747728; called by muse, mutect2, varscan2
- CCR5 | c.170A>T p.N57I | Missense Mutation (SNP) | VAF 68/225 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.148); catalogued as COSV52750894; called by muse, mutect2, varscan2
- CD163 | c.2267T>C p.V756A | Missense Mutation (SNP) | VAF 38/155 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV63129708; called by muse, mutect2, varscan2
- CD180 | c.883C>T p.Q295* | Nonsense Mutation (SNP) | VAF 44/106 reads (42%) | catalogued as rs1181496324, COSV56516941; called by muse, mutect2, varscan2
- CD1C | c.666G>T p.L222F | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.727); catalogued as rs1188158151, COSV63805596; called by muse, mutect2, varscan2
- CD276 | c.1033C>T p.R345W | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs754336923, COSV59202678; called by muse, mutect2, varscan2
- CD5L | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63821147, COSV63822911; called by muse, mutect2, varscan2
- CD6 | c.1283G>A p.G428E | Missense Mutation (SNP) | VAF 67/194 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57835968; called by muse, mutect2, varscan2
- CDC23 | c.362C>T p.S121F | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67508291; called by muse, mutect2, varscan2
- CDH12 | c.1285G>A p.D429N | Missense Mutation (SNP) | VAF 63/195 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.795); catalogued as rs550427767, COSV66389347, COSV66421563; called by muse, mutect2, varscan2
- CDK15 | c.505C>T p.H169Y (on ENST00000652192 / NM_001366386.2; = p.H118Y on NM_139158.2) | Missense Mutation (SNP) | VAF 26/153 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV53631635; called by muse, mutect2, varscan2
- CELF4 | c.941C>T p.P314L | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.141); catalogued as COSV58447188; called by muse, mutect2, varscan2
- CFAP44 | c.2770A>G p.S924G | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.423); catalogued as COSV55608761; called by muse, mutect2, varscan2
- CFAP52 | c.452G>A p.S151N | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.919); catalogued as rs756537922, COSV55343029; called by muse, mutect2, varscan2
- CFAP54 | c.7115C>T p.S2372F | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.697); catalogued as rs894088687, COSV61570780; called by muse, mutect2, varscan2
- CFAP54 | c.7511G>A p.G2504E | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV61570784; called by muse, mutect2, varscan2
- CFAP61 | c.583G>A p.D195N | Missense Mutation (SNP) | VAF 55/154 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as rs371793125, COSV55639118; called by muse, mutect2, varscan2
- CFAP70 | c.2692G>A p.E898K | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (0.59); PolyPhen benign (0.316); catalogued as rs1011917401, COSV60281145; called by muse, mutect2, varscan2
- CFH | c.415C>T p.P139S | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM094717, COSV62776377, COSV62777251; called by muse, mutect2, varscan2
- CFHR2 | c.485C>T p.S162L | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.3); catalogued as COSV104427139, COSV66380510; called by muse, mutect2, varscan2
- CFHR4 | c.1339T>A p.F447I (on ENST00000367416 / NM_001201551.2; = p.F201I on NM_006684.5) | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV52224713; called by muse, mutect2, varscan2
- CFHR4 | c.1592G>A p.G531E (on ENST00000367416 / NM_001201551.2; = p.G285E on NM_006684.5) | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.379); catalogued as COSV52224734; called by muse, mutect2, varscan2
- CFHR5 | c.379A>T p.I127F | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56818276; called by muse, varscan2
- CFP | c.269C>T p.S90L | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1476877032, COSV55949750; called by muse, mutect2
- CHD1L | c.276A>T p.L92F | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.042); catalogued as COSV63612846; called by muse, mutect2, varscan2
- CHD2 | c.1621C>T p.P541S | Missense Mutation (SNP) | VAF 55/123 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV67706875; called by muse, mutect2, varscan2
- CHD8 | c.1109C>T p.T370I (on ENST00000646647 / NM_001170629.2; = p.T91I on NM_020920.4) | Missense Mutation (SNP) | VAF 18/164 reads (11%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.005); catalogued as COSV67869722; called by muse, mutect2, varscan2
- CHGB | c.1354C>T p.Q452* | Nonsense Mutation (SNP) | VAF 44/156 reads (28%) | catalogued as COSV100973029, COSV66759641; called by muse, mutect2, varscan2
- CHRD | c.2864C>A p.S955Y | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as COSV52605669; called by muse, mutect2, varscan2
- CHRM2 | c.227C>T p.S76F | Missense Mutation (SNP) | VAF 75/162 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57766030; called by muse, mutect2, varscan2
- CHRM3 | c.1306G>A p.D436N | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.37); PolyPhen benign (0.012); catalogued as rs1331443076, COSV55081050; called by muse, mutect2, varscan2
- CHRNA1 | c.315G>A p.W105* (on ENST00000261007 / NM_001039523.3; = p.W80* on NM_000079.4) | Nonsense Mutation (SNP) | VAF 15/53 reads (28%) | catalogued as COSV53681713; called by muse, mutect2, varscan2
- CHRNA10 | c.610G>T p.V204L | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.94); PolyPhen benign (0.105); catalogued as COSV51702926, COSV51704391; called by muse, mutect2, varscan2
- CHRNB2 | c.701C>T p.P234L | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1450162279, COSV63807739; called by muse, mutect2, varscan2
- CHRNB3 | c.368G>A p.G123D | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV51493338; called by muse, varscan2
- CHRNB3 | c.410C>T p.S137L | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as rs1418024205, COSV51493359, COSV51495659; called by muse, varscan2
- CHST15 | c.323C>T p.S108L | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.051); catalogued as rs1211830928, COSV60560360; called by muse, mutect2, varscan2
- CLC | c.380G>A p.W127* | Nonsense Mutation (SNP) | VAF 89/202 reads (44%) | catalogued as COSV55684772; called by muse, mutect2, varscan2
- CLCA4 | c.944G>A p.G315E | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.651); catalogued as COSV55366472; called by muse, mutect2, varscan2
- CLDN17 | c.55G>A p.V19M | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as rs1434018029, COSV54522282; called by muse, mutect2, varscan2
- CLDN6 | c.418G>A p.A140T | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.735); catalogued as COSV58508905; called by muse, mutect2
- CLEC4F | c.1051C>T p.R351C | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs1426229523, COSV55478290; called by muse, mutect2, varscan2
- CLIP4 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.751); catalogued as rs755957985, COSV60747733; called by muse, mutect2
- CLIP4 | c.1567C>T p.H523Y | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT tolerated (0.39); PolyPhen benign (0.019); catalogued as COSV60747743; called by muse, mutect2, varscan2
- CNBD1 | c.677C>T p.S226L | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs1184694350, COSV72975909; called by muse, mutect2, varscan2
- CNFN | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 7/9 reads (78%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as COSV55771663; called by muse, mutect2, varscan2
- CNGB1 | c.1558G>A p.D520N | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as COSV51897949; called by muse, mutect2
- CNKSR2 | c.2515G>A p.G839R | Missense Mutation (SNP) | VAF 46/60 reads (77%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); catalogued as COSV54249876; called by muse, varscan2
- CNOT8 | c.760A>T p.K254* | Nonsense Mutation (SNP) | VAF 22/88 reads (25%) | catalogued as COSV53585037; called by muse, mutect2, varscan2
- CNTN4 | c.963A>T p.K321N | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.288); catalogued as rs1317262739, COSV61868224; called by muse, mutect2, varscan2
- CNTNAP2 | c.392G>A p.G131E | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.58); PolyPhen benign (0.359); catalogued as COSV62147964; called by muse, mutect2
- CNTNAP4 | c.3569C>T p.P1190L | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV56666168; called by muse, mutect2, varscan2
- COG6 | c.1811T>C p.L604P | Missense Mutation (SNP) | VAF 43/137 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV62995150; called by muse, mutect2, varscan2
- COG7 | c.1361C>T p.P454L | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV56149205; called by muse, mutect2, varscan2
- COL11A2 | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs1554226286, COSV59493786, COSV59499564; ClinVar: likely benign; called by muse, mutect2, varscan2
- COL14A1 | c.5254C>T p.P1752S | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as COSV52847666; called by muse, mutect2, varscan2
- COL21A1 | c.2353G>A p.G785R | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.067); catalogued as COSV55154263; called by muse, mutect2, varscan2
- COL21A1 | c.2102G>A p.G701E | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55152222; called by muse, varscan2
- COL22A1 | c.2968G>A p.G990R | Missense Mutation (SNP) | VAF 47/128 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57324460; called by muse, mutect2, varscan2
- COL4A4 | c.3592G>A p.G1198R | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1278360882, COSV100306356; called by muse, mutect2
- COL5A1 | c.1078G>A p.G360R | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.023); catalogued as COSV65665406; called by muse, mutect2, varscan2
- COL5A1 | c.1949C>T p.P650L | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.981); catalogued as rs150890005; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL5A2 | c.2905G>A p.G969R | Missense Mutation (SNP) | VAF 55/119 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66407299; called by muse, mutect2, varscan2
- COL5A2 | c.2104G>A p.G702R | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772811492, COSV66407304; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL5A3 | c.3001G>A p.G1001R | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53406525, COSV53415988; called by muse, mutect2, varscan2
- COL7A1 | c.5308-1G>A p.X1770_splice | Splice Site (SNP) | VAF 16/69 reads (23%) | catalogued as COSV60391571; called by muse, mutect2, varscan2
- COL9A1 | c.1837G>A p.G613R | Missense Mutation (SNP) | VAF 125/278 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57879027; called by muse, mutect2, varscan2
- COPS3 | c.701T>A p.L234* | Nonsense Mutation (SNP) | VAF 8/36 reads (22%) | catalogued as COSV52004288; called by muse, mutect2, varscan2
- CPLX3 | c.424C>T p.Q142* | Nonsense Mutation (SNP) | VAF 20/54 reads (37%) | catalogued as COSV59000699; called by muse, mutect2, varscan2
- CPN2 | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.039); catalogued as COSV60469573; called by muse, mutect2, varscan2
- CPOX | c.905A>G p.E302G | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.382); catalogued as COSV51637495; called by muse, mutect2, varscan2
- CPXCR1 | c.109G>A p.D37N | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT tolerated (0.12); PolyPhen benign (0.181); catalogued as COSV52161147; called by muse, mutect2, varscan2
- CR1 | c.4165C>T p.L1389F | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.798); catalogued as COSV65456076; called by muse, mutect2, varscan2
- CRB1 | c.1832C>T p.S611F | Missense Mutation (SNP) | VAF 53/101 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); catalogued as COSV66328793; called by muse, mutect2, varscan2
- CRYBB2 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 32/50 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.262); catalogued as rs866268820, COSV68005292; called by muse, mutect2, varscan2
- CRYBG1 | c.4102G>A p.E1368K | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.967); catalogued as COSV64810837; called by muse, mutect2, varscan2
- CSF2RA | c.464G>A p.R155Q | Missense Mutation (SNP) | VAF 57/173 reads (33%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs200344796, COSV62623641; ClinVar: likely benign; called by muse, mutect2, varscan2
- CSMD1 | c.10382G>A p.G3461E (on ENST00000520002; = p.G3460E on NM_033225.6) | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1236928062, COSV59284695, COSV59316629; called by muse, mutect2, varscan2
- CSMD1 | c.3229C>T p.R1077C (on ENST00000520002; = p.R1076C on NM_033225.6) | Missense Mutation (SNP) | VAF 50/131 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867742507, COSV59279573, COSV59288383; called by muse, mutect2, varscan2
- CSMD1 | c.437G>A p.G146E | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV68171058; called by muse, mutect2, varscan2
- CSMD2 | c.2117G>A p.S706N | Missense Mutation (SNP) | VAF 46/97 reads (47%) | SIFT tolerated (0.54); PolyPhen benign (0.029); catalogued as COSV53882563; called by muse, mutect2, varscan2
- CSMD2 | c.1949G>A p.G650E | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs868169530, COSV53878136; called by muse, mutect2, varscan2
- CSMD2 | c.1703C>T p.S568L | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV53882610; called by muse, mutect2, varscan2
- CSMD3 | c.1211C>T p.S404L | Missense Mutation (SNP) | VAF 50/141 reads (35%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.055); catalogued as rs867207529, COSV52108624, COSV99842288; called by muse, mutect2, varscan2
- CSRP3 | c.484A>T p.K162* | Nonsense Mutation (SNP) | VAF 39/116 reads (34%) | catalogued as COSV56388980; called by muse, mutect2, varscan2
- CTCFL | c.1084C>T p.R362* | Nonsense Mutation (SNP) | VAF 60/166 reads (36%) | catalogued as rs1256967428, COSV54771107; called by muse, mutect2, varscan2
- CUL7 | c.735C>T p.V245= | Splice Region (SNP) | VAF 57/116 reads (49%) | catalogued as COSV54813398; called by muse, mutect2, varscan2
- CWH43 | c.1145C>T p.S382F | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.243); catalogued as COSV56936123; called by muse, mutect2, varscan2
- CYP11B1 | c.244G>A p.D82N | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as rs762347776, COSV52825046; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- CYP2C18 | c.550C>T p.H184Y | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.033); catalogued as COSV53669835; called by muse, mutect2, varscan2
- CYP3A5 | c.321T>C p.S107= | Splice Region (SNP) | VAF 9/21 reads (43%) | catalogued as COSV56118627; called by muse, mutect2
- CYP3A7 | c.473G>A p.R158K | Missense Mutation (SNP) | VAF 55/154 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1390015837, COSV60480593, COSV60482433; called by muse, mutect2, varscan2
- CYP4A11 | c.1501G>A p.G501R | Missense Mutation (SNP) | VAF 49/87 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60222200; called by muse, mutect2, varscan2
- CYP4F22 | c.851G>A p.R284Q | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as rs755129541, COSV54106627; called by muse, mutect2, varscan2
- CYP4V2 | c.1178C>T p.P393L | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1344497909, COSV66505068; called by muse, mutect2, varscan2
- CYP4Z1 | c.730C>T p.Q244* | Nonsense Mutation (SNP) | VAF 17/67 reads (25%) | catalogued as COSV100497541; called by muse, mutect2, varscan2
- CYP7A1 | c.1097C>T p.A366V | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.383); catalogued as rs1168837944, COSV100052202; called by muse, mutect2, varscan2
- DAAM2 | c.1855C>T p.P619S | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs773987078, COSV51302909; called by muse, mutect2, varscan2
- DACH1 | c.1834C>T p.P612S (on ENST00000619232 / NM_001366712.1; = p.P358S on NM_004392.6) | Missense Mutation (SNP) | VAF 51/239 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV57490296; called by muse, mutect2, varscan2
- DCAF12L2 | c.745G>A p.D249N | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT tolerated (0.37); PolyPhen benign (0.343); catalogued as COSV63580402; called by muse, mutect2, varscan2
- DCLK3 | c.373C>T p.L125F | Missense Mutation (SNP) | VAF 72/214 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.293); catalogued as rs1412012181, COSV69362279; called by muse, mutect2, varscan2
- DCSTAMP | c.1135C>T p.P379S | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.108); catalogued as rs377712228; called by muse, mutect2, varscan2
- DEFB134 | c.44A>T p.D15V | Missense Mutation (SNP) | VAF 47/136 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.218); catalogued as COSV66363090, COSV66363253; called by muse, mutect2, varscan2
- DHH | c.347A>G p.N116S | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV57201389; called by muse, mutect2, varscan2
- DIP2B | c.1655-1G>A p.X552_splice | Splice Site (SNP) | VAF 20/60 reads (33%) | catalogued as COSV56579198; called by muse, mutect2, varscan2
- DIPK2B | c.1291G>A p.D431N | Missense Mutation (SNP) | VAF 49/72 reads (68%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as rs747175485, COSV67640888; called by muse, mutect2, varscan2
- DISP1 | c.1666C>T p.P556S | Missense Mutation (SNP) | VAF 125/586 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52655014; called by muse, mutect2, varscan2
- DISP1 | c.3299C>T p.S1100F | Missense Mutation (SNP) | VAF 261/560 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52655032; called by muse, mutect2, varscan2
- DKKL1 | c.530G>A p.R177Q | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.023); catalogued as rs768795944, COSV99678625; called by muse, mutect2
- DLGAP4 | c.1010G>A p.G337D | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV59414642; called by muse, mutect2, varscan2
- DMBT1 | c.7532C>T p.S2511L (on ENST00000338354 / NM_001377530.1; = p.S1754L on NM_004406.3) | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as rs1160076916, COSV57535215; called by muse, mutect2, varscan2
- DNAH11 | c.10037G>A p.R3346Q | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as rs761713335, COSV60941356; called by muse, mutect2, varscan2
- DNAH17 | c.6551C>T p.S2184F | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV67750047; called by muse, mutect2, varscan2
- DNAH3 | c.11191G>A p.E3731K | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV54505056; called by muse, mutect2, varscan2
- DNAH5 | c.11102C>T p.P3701L | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54205311; called by muse, mutect2, varscan2
- DNAH5 | c.4633G>A p.E1545K | Missense Mutation (SNP) | VAF 41/134 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1176527436, COSV54205345; called by muse, mutect2, varscan2
- DNAH5 | c.2225G>A p.R742Q | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs560939419, COSV54203651, COSV99453001; called by muse, mutect2
- DNAH7 | c.7351G>A p.D2451N | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV56753131, COSV56762425; called by muse, mutect2, varscan2
- DNAH7 | c.3184G>A p.E1062K | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56753139; called by muse, mutect2, varscan2
- DNAH9 | c.3790G>A p.E1264K | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.035); catalogued as rs756428546, COSV52335454; called by muse, mutect2, varscan2
- DNAH9 | c.5764G>A p.D1922N | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52335463; called by muse, mutect2, varscan2
- DNAI2 | c.242G>A p.W81* | Nonsense Mutation (SNP) | VAF 50/94 reads (53%) | catalogued as COSV56756972; called by muse, mutect2, varscan2
- DNAJB13 | c.94C>T p.H32Y | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60268592; called by muse, mutect2, varscan2
- DNAJC13 | c.3998C>T p.P1333L | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53446062, COSV99607960; called by muse, mutect2, varscan2
- DNAJC13 | c.6003A>T p.E2001D | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV53446080; called by muse, mutect2, varscan2
- DNM3 | c.1934A>G p.Q645R (on ENST00000355305 / NM_001350206.2; = p.Q639R on NM_015569.5) | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.031); catalogued as COSV62453405; called by muse, mutect2
- DNM3 | c.1936G>A p.A646T (on ENST00000355305 / NM_001350206.2; = p.A640T on NM_015569.5) | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs751617803, COSV62453411; called by muse, mutect2
- DOCK3 | c.1174C>T p.R392W | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747625031, COSV56500936; called by muse, mutect2, varscan2
- DOCK3 | c.5022G>A p.M1674I | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.006); catalogued as COSV56504681; called by muse, mutect2, varscan2
- DOCK5 | c.1561G>A p.E521K | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.426); catalogued as COSV52396440; called by muse, mutect2, varscan2
- DPH2 | c.548C>T p.P183L | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.463); catalogued as COSV52542557; called by muse, mutect2, varscan2
- DPYD | c.2482G>A p.E828K | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT tolerated (0.17); PolyPhen benign (0.029); catalogued as rs200687447, CM145312, COSV64591456; called by muse, mutect2, varscan2
- DPYSL3 | c.1195G>A p.G399R | Missense Mutation (SNP) | VAF 72/168 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58324213; called by muse, mutect2, varscan2
- DRGX | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.081); catalogued as COSV65135819; called by muse, mutect2, varscan2
- DSC1 | c.2185G>A p.A729T | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV57142067; called by muse, mutect2, varscan2
- DSC2 | c.2582G>A p.G861E | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51861441; called by muse, mutect2, varscan2
- DSCAM | c.4331G>A p.G1444E | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68021365; called by muse, mutect2, varscan2
- DSCAM | c.3820G>A p.E1274K | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as rs903334101; called by muse, mutect2, varscan2
- DSP | c.4954G>A p.E1652K | Missense Mutation (SNP) | VAF 55/157 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.141); catalogued as rs267601119, COSV65791352; called by muse, mutect2, varscan2
- DTX3 | c.418C>T p.P140S | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.8); PolyPhen benign (0.109); catalogued as rs775422629, COSV99677614; called by muse, varscan2
- DYSF | c.4451C>T p.S1484F | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50270839; called by muse, mutect2, varscan2
- EBPL | c.616C>T p.Q206* | Nonsense Mutation (SNP) | VAF 27/77 reads (35%) | catalogued as COSV54431549; called by muse, mutect2, varscan2
- ECHDC2 | c.643G>A p.E215K (on ENST00000371522 / NM_001198961.2; = p.E184K on NM_018281.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.352); catalogued as rs1474349589, COSV64300227; called by muse, mutect2, varscan2
- ECPAS | c.3935G>A p.R1312Q | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.265); catalogued as rs570259199, COSV52192155; called by muse, mutect2, varscan2
- EEF2K | c.454C>T p.L152F | Missense Mutation (SNP) | VAF 31/160 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53778947; called by muse, mutect2, varscan2
- EFCAB6 | c.3437C>T p.A1146V | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated (0.08); PolyPhen benign (0.044); catalogued as COSV53058584; called by muse, mutect2
- EGF | c.299G>A p.R100K | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.038); catalogued as COSV54475886, COSV99491287; called by muse, mutect2, varscan2
- EGFL6 | c.1017G>A p.M339I | Missense Mutation (SNP) | VAF 27/36 reads (75%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV63632904; called by muse, mutect2, varscan2
- EIF4G3 | c.4128G>A p.W1376* | Nonsense Mutation (SNP) | VAF 10/40 reads (25%) | catalogued as COSV51674663; called by muse, mutect2, varscan2
- ELAVL4 | c.692G>A p.R231Q | Missense Mutation (SNP) | VAF 48/98 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as rs1345370346, COSV63914597; called by muse, mutect2, varscan2
- ENAH | c.263G>A p.G88D | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52865319; called by muse, mutect2, varscan2
- ENAM | c.1285C>T p.R429C | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.663); catalogued as rs1343700582, COSV68535280; called by muse, mutect2, varscan2
- ENTPD4 | c.134C>T p.S45L | Missense Mutation (SNP) | VAF 45/107 reads (42%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV62268187; called by muse, mutect2, varscan2
- EP300 | c.4879C>T p.R1627W | Missense Mutation (SNP) | VAF 44/80 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV54325405, COSV54343776; called by muse, mutect2, varscan2
- EPB41L4A | c.340C>T p.Q114* | Nonsense Mutation (SNP) | VAF 11/26 reads (42%) | catalogued as COSV54863061; called by muse, mutect2
- EPG5 | c.5224G>A p.E1742K | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.814); catalogued as COSV56344902, COSV56352792; called by muse, mutect2, varscan2
- EPHA6 | c.1559T>G p.F520C | Missense Mutation (SNP) | VAF 46/120 reads (38%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.819); catalogued as COSV67560228; called by muse, mutect2, varscan2
- EPX | c.583C>T p.L195F | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.206); catalogued as rs748539431, COSV56595052, COSV99836751; called by muse, mutect2, varscan2
- ERBB4 | c.1715C>T p.P572L | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.16); catalogued as rs759551723, COSV53504601; called by muse, mutect2, varscan2
- ERC2 | c.1085G>A p.R362Q | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); catalogued as rs1449372814, COSV55602692; called by muse, varscan2
- EREG | c.439C>T p.R147* | Nonsense Mutation (SNP) | VAF 11/44 reads (25%) | catalogued as rs376236920, COSV55262382; called by muse, mutect2, varscan2
- ESCO2 | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.083); catalogued as COSV59413387; called by muse, mutect2, varscan2
- ESRP1 | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 192/568 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.414); catalogued as COSV64407953; called by muse, mutect2, varscan2
- ETNPPL | c.1102G>A p.G368R | Missense Mutation (SNP) | VAF 34/165 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs867297049, COSV56594688; called by muse, mutect2, varscan2
- EXD2 | c.1382C>T p.S461F (on ENST00000312994 / NM_001193362.1; = p.S336F on NM_018199.3) | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs1177886071, COSV57278152; called by muse, mutect2, varscan2
- EXTL3 | c.1631C>T p.P544L | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.282); catalogued as rs1375551891, COSV55036825; called by muse, mutect2, varscan2
- EYA2 | c.1436G>A p.G479E | Missense Mutation (SNP) | VAF 61/167 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57938790; called by muse, mutect2, varscan2
- F5 | c.4135C>T p.L1379F | Missense Mutation (SNP) | VAF 38/199 reads (19%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.003); catalogued as COSV63120974; called by muse, mutect2, varscan2
- FAM135B | c.3632G>A p.R1211Q | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs867471938, COSV52703558; called by muse, mutect2, varscan2
- FAM171A1 | c.1627C>T p.R543* | Nonsense Mutation (SNP) | VAF 24/163 reads (15%) | catalogued as COSV65313561; called by muse, mutect2, varscan2
- FAM199X | c.948T>A p.S316R | Missense Mutation (SNP) | VAF 33/136 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.975); catalogued as COSV55433199; called by muse, mutect2, varscan2
- FAM217A | c.1483C>T p.L495F | Missense Mutation (SNP) | VAF 44/93 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV51158962; called by muse, mutect2
- FAM217A | c.1481C>T p.S494F | Missense Mutation (SNP) | VAF 43/92 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV51158971; called by muse, mutect2
- FAM47C | c.2003C>G p.P668R | Missense Mutation (SNP) | VAF 33/45 reads (73%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.729); catalogued as COSV63723919, COSV63728732, COSV63728956, COSV63730909; called by muse, mutect2, varscan2
- FAM83B | c.2033G>A p.G678E | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as COSV60919550; called by muse, mutect2, varscan2
- FAM83H | c.2515C>T p.Q839* | Nonsense Mutation (SNP) | VAF 5/20 reads (25%) | catalogued as COSV62027427; called by muse, mutect2, varscan2
- FAP | c.1153G>A p.E385K | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated (0.47); PolyPhen benign (0.017); catalogued as COSV51859418; called by muse, mutect2, varscan2
- FAT3 | c.6244C>T p.P2082S | Missense Mutation (SNP) | VAF 246/773 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53079037; called by muse, mutect2, varscan2
- FBXO15 | c.380C>T p.S127L | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.25); PolyPhen benign (0.122); catalogued as rs866297725, COSV54043024; called by muse, mutect2, varscan2
- FBXO30 | c.319T>G p.Y107D | Missense Mutation (SNP) | VAF 61/107 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV52790279; called by muse, mutect2, varscan2
- FBXO39 | c.1255G>A p.E419K | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.051); catalogued as COSV58621074; called by muse, mutect2, varscan2
- FBXW2 | c.343G>A p.D115N | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.956); catalogued as COSV100535101; called by muse, mutect2, varscan2
- FCN2 | c.316A>T p.K106* | Nonsense Mutation (SNP) | VAF 30/69 reads (43%) | catalogued as COSV52475940; called by muse, mutect2
- FCRL5 | c.1207G>A p.A403T | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.64); catalogued as COSV62511588; called by muse, mutect2, varscan2
- FER1L6 | c.1813G>A p.D605N | Missense Mutation (SNP) | VAF 81/225 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.232); catalogued as COSV67548272; called by muse, mutect2, varscan2
- FETUB | c.898C>T p.P300S | Missense Mutation (SNP) | VAF 37/146 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.109); catalogued as COSV54004694; called by muse, mutect2, varscan2
- FFAR2 | c.746G>A p.R249K | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55831792; called by muse, mutect2, varscan2
- FGA | c.151G>T p.D51Y | Missense Mutation (SNP) | VAF 51/112 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV57393320; called by muse, mutect2, varscan2
- FGD5 | c.2749G>A p.D917N | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.759); catalogued as COSV53237729; called by muse, mutect2, varscan2
- FGL2 | c.788A>G p.N263S | Missense Mutation (SNP) | VAF 47/122 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.054); catalogued as COSV50380283; called by muse, mutect2, varscan2
- FILIP1L | c.1355G>A p.R452K (on ENST00000354552 / NM_182909.3; = p.R212K on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58765150; called by muse, mutect2, varscan2
- FKBP9 | c.1249A>C p.N417H | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.873); catalogued as COSV54227959; called by muse, mutect2, varscan2
- FLG2 | c.4010C>T p.S1337F | Missense Mutation (SNP) | VAF 46/182 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.496); catalogued as rs746819915, COSV66166799; called by muse, mutect2, varscan2
- FLNB | c.2386G>A p.D796N | Missense Mutation (SNP) | VAF 73/192 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV55871241; called by muse, mutect2, varscan2
- FLNC | c.4070G>A p.G1357E | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57950918; called by muse, mutect2, varscan2
- FLT3 | c.631C>T p.P211S | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.82); PolyPhen benign (0.003); catalogued as COSV54045314; called by muse, mutect2, varscan2
- FLT3 | c.149C>T p.S50L | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.054); catalogued as rs757157975, COSV54045332; called by muse, mutect2, varscan2
- FMN2 | c.5080G>C p.V1694L | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.081); catalogued as COSV60418249; called by muse, mutect2, varscan2
- FMO1 | c.1235G>A p.R412K | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.038); catalogued as COSV61444694; called by muse, mutect2, varscan2
- FN1 | c.1844T>C p.F615S | Missense Mutation (SNP) | VAF 23/38 reads (61%) | SIFT tolerated (0.1); PolyPhen benign (0.106); catalogued as COSV60547183; called by muse, mutect2, varscan2
- FNBP4 | c.1585C>T p.Q529* | Nonsense Mutation (SNP) | VAF 12/30 reads (40%) | catalogued as COSV55446519; called by muse, mutect2, varscan2
- FREM2 | c.2099C>T p.P700L | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.377); catalogued as rs1323665933, COSV54829499; called by muse, mutect2, varscan2
- FREM2 | c.6526G>A p.D2176N | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54829510; called by muse, mutect2, varscan2
- FREM2 | c.9415G>A p.E3139K | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0); catalogued as rs746196338, COSV54829523; called by muse, mutect2, varscan2
- FRMD3 | c.1190G>A p.G397D | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV58455244; called by muse, mutect2, varscan2
- FRMD3 | c.412C>T p.H138Y | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV58455269; called by muse, mutect2, varscan2
- FRMD3 | c.226C>T p.R76C | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs770440183, COSV58455289; called by muse, mutect2, varscan2
- FRMPD2 | c.2233C>T p.L745F | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.118); catalogued as COSV59715397; called by muse, mutect2, varscan2
- FSD2 | c.1135C>T p.P379S | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV58008739; called by muse, mutect2
- FUS | c.191-2A>T p.X64_splice | Splice Site (SNP) | VAF 27/156 reads (17%) | catalogued as COSV54215581; called by muse, mutect2, varscan2
- FZD2 | c.1470G>A p.W490* | Nonsense Mutation (SNP) | VAF 11/22 reads (50%) | catalogued as COSV59528181; called by muse, mutect2, varscan2
- GABRB2 | c.683C>T p.S228F | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as rs1286245289, COSV50903564; called by muse, mutect2, varscan2
- GABRG1 | c.586C>T p.P196S | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54950303; called by muse, mutect2, varscan2
- GABRG1 | c.98G>A p.G33E | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.994); catalogued as COSV54950313; called by muse, mutect2, varscan2
- GABRP | c.554G>A p.G185E | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.71); PolyPhen benign (0.015); catalogued as COSV54661459; called by muse, mutect2, varscan2
- GALNT12 | c.664G>A p.D222N | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs947666286, COSV66662167; called by muse, mutect2
- GALNT14 | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61102270; called by muse, mutect2, varscan2
- GALNT17 | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 54/115 reads (47%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.709); catalogued as rs866308070, COSV100355048, COSV61148982; called by muse, mutect2, varscan2
- GALNT9 | c.1120C>T p.R374C (on ENST00000328957 / NM_001122636.2; = p.R8C on NM_021808.3) | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1352925080, COSV61096137; called by muse, mutect2, varscan2
- GALP | c.315G>A p.M105I | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs867751771, COSV61999251; called by muse, mutect2, varscan2
- GATB | c.539C>T p.P180L | Missense Mutation (SNP) | VAF 41/167 reads (25%) | SIFT tolerated (0.48); PolyPhen benign (0.015); catalogued as COSV56128998; called by muse, mutect2, varscan2
- GCK | c.188G>A p.R63H | Missense Mutation (SNP) | VAF 72/383 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.804); catalogued as rs746444094, COSV61752608; called by muse, mutect2, varscan2
- GDNF | c.455C>T p.A152V | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.035); catalogued as COSV58478315; called by muse, mutect2, varscan2
- GFM2 | c.1382C>T p.A461V | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.358); catalogued as rs575347222, COSV57189792; called by muse, mutect2, varscan2
- GFRA1 | c.590G>C p.R197P | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62602330; called by muse, mutect2, varscan2
- GK2 | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 50/115 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs1321996211, COSV62626188; called by muse, mutect2, varscan2
- GLRB | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs866482989, COSV52412584, COSV52414164; called by muse, varscan2
- GLRB | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 60/131 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.052); catalogued as rs568062230, COSV52413337; called by muse, varscan2
- GLT6D1 | c.668G>A p.G223E | Missense Mutation (SNP) | VAF 41/95 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); catalogued as COSV65627061; called by muse, mutect2, varscan2
- GLT8D2 | c.857C>T p.P286L | Missense Mutation (SNP) | VAF 26/41 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV62561127; called by muse, mutect2
- GLYATL2 | c.350T>C p.V117A | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT tolerated (0.68); PolyPhen benign (0.031); catalogued as rs375132339; called by muse, mutect2, varscan2
- GMEB1 | c.1187C>T p.P396L | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT tolerated (0.52); PolyPhen benign (0.051); catalogued as rs753788875, COSV53793003; called by muse, mutect2, varscan2
- GPAT3 | c.932C>T p.S311L | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1334375375, COSV52355423; called by muse, mutect2, varscan2
- GPC3 | c.1160G>A p.R387Q | Missense Mutation (SNP) | VAF 36/46 reads (78%) | SIFT deleterious (0.02); PolyPhen benign (0.19); catalogued as rs145280221, COSV63659408; ClinVar: benign; called by muse, mutect2, varscan2
- GPR149 | c.1777C>T p.R593* | Nonsense Mutation (SNP) | VAF 45/141 reads (32%) | catalogued as rs774432061, COSV67665913; called by muse, mutect2, varscan2
- GPR63 | c.647G>A p.G216E | Missense Mutation (SNP) | VAF 44/80 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57739676; called by muse, mutect2, varscan2
- GPR83 | c.1139C>T p.S380F | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.208); catalogued as COSV54717608; called by muse, mutect2
- GPR83 | c.901T>C p.F301L | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs749125758, COSV54717619; called by muse, mutect2, varscan2
- GPRC5C | c.377C>A p.T126N (on ENST00000652232; = p.T81N on NM_018653.4) | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.139); catalogued as COSV61235479; called by muse, mutect2, varscan2
- GRIA1 | c.2714G>A p.G905E | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.045); catalogued as COSV53589094, COSV53597833; called by muse, mutect2
- GRIK3 | c.1265G>A p.G422D | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as COSV66135924; called by muse, mutect2, varscan2
- GRIP1 | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); catalogued as COSV54015940, COSV99669888; called by muse, mutect2, varscan2
- GRIP2 | c.1207G>A p.E403K (on ENST00000619221; = p.E306K on NM_001080423.4) | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.761); catalogued as COSV56119812, COSV56121348; called by muse, mutect2, varscan2
- GRK5 | c.202C>T p.R68W | Missense Mutation (SNP) | VAF 44/121 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs766100398, COSV64865624; called by muse, mutect2, varscan2
- GRM3 | c.53G>A p.G18E | Missense Mutation (SNP) | VAF 46/127 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0.017); catalogued as COSV64466563; called by muse, mutect2, varscan2
- GSN | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.025); catalogued as rs752677417, COSV57994782; called by muse, mutect2, varscan2
- GTPBP4 | c.229C>T p.P77S | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62550203; called by muse, mutect2, varscan2
- GUCY1A1 | c.1198C>T p.L400F | Missense Mutation (SNP) | VAF 32/54 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1441952852, COSV56649365; called by muse, mutect2, varscan2
- GUCY1A2 | c.1274C>T p.P425L | Missense Mutation (SNP) | VAF 29/44 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56478639; called by muse, mutect2, varscan2
- GUCY2C | c.2581G>A p.D861N | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755853968, COSV53786996; called by muse, mutect2, varscan2
- GUCY2D | c.2273A>T p.Q758L | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.139); catalogued as COSV54694577; called by muse, mutect2, varscan2
- GYS2 | c.589C>T p.P197S | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.883); catalogued as COSV53920759; called by muse, mutect2, varscan2
- HAO2 | c.509G>A p.R170Q | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.155); catalogued as rs144704512; called by muse, mutect2, varscan2
- HAO2 | c.904C>T p.P302S | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV58037964; called by mutect2, varscan2
- HAPLN3 | c.643G>A p.G215S | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61356520; called by muse, mutect2, varscan2
- HAUS5 | c.1460C>T p.S487F | Missense Mutation (SNP) | VAF 29/163 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV99177908; called by muse, mutect2, varscan2
- HCFC2 | c.1396C>T p.P466S | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV57558006; called by muse, mutect2, varscan2
- HDC | c.1276G>A p.E426K | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0.014); catalogued as COSV51068362; called by muse, mutect2, varscan2
- HEATR6 | c.3006T>G p.N1002K | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV51743809; called by muse, mutect2, varscan2
- HECW2 | c.544C>T p.R182* | Nonsense Mutation (SNP) | VAF 41/82 reads (50%) | catalogued as COSV53650291; called by muse, mutect2, varscan2
- HEPHL1 | c.593C>T p.S198F | Missense Mutation (SNP) | VAF 42/126 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59889680; called by muse, mutect2, varscan2
- HEPHL1 | c.2858G>A p.R953Q | Missense Mutation (SNP) | VAF 66/175 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs939355851, COSV59889696; called by muse, mutect2, varscan2
- HFE | c.29T>A p.L10H | Missense Mutation (SNP) | VAF 41/151 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as COSV58512515; called by muse, mutect2, varscan2
- HGF | c.647G>A p.G216E | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV55945708, COSV55957020; called by muse, mutect2, varscan2
- HIVEP3 | c.2056G>A p.E686K | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs1430167786, COSV56010100; called by muse, mutect2, varscan2
- HK2 | c.343C>T p.P115S | Missense Mutation (SNP) | VAF 112/359 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV51873456; called by muse, mutect2, varscan2
- HLA-DMB | c.560G>A p.G187E | Missense Mutation (SNP) | VAF 58/114 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.39); catalogued as COSV101186856, COSV66870588; called by muse, mutect2
- HLA-DQA1 | c.485G>A p.S162N | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0.01); catalogued as COSV58237411; called by muse, mutect2, varscan2
- HMCN1 | c.754A>G p.S252G | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV54879363; called by muse, mutect2, varscan2
- HNRNPCL1 | c.296G>A p.R99Q | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.63); catalogued as rs150230498; called by muse, mutect2, varscan2
- HNRNPUL1 | c.836C>T p.P279L | Missense Mutation (SNP) | VAF 47/114 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.246); catalogued as COSV54560273; called by muse, mutect2, varscan2
- HOXB3 | c.88G>A p.D30N | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV61142687, COSV61144832; called by muse, mutect2, varscan2
- HPN | c.677C>T p.S226F | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.85); catalogued as COSV52882294; called by muse, mutect2, varscan2
- HPSE | c.815G>A p.R272Q | Missense Mutation (SNP) | VAF 42/186 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs756139166, COSV60985519; called by muse, mutect2, varscan2
- HSD11B1 | c.172G>A p.G58R | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54826040; called by muse, mutect2, varscan2
- HSH2D | c.1003G>A p.D335N | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.885); catalogued as rs373698635; called by muse, mutect2, varscan2
- HTR4 | c.328C>T p.H110Y | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867725219, COSV58789896; called by muse, mutect2, varscan2
- HTRA1 | c.826G>A p.G276R | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64563453; called by muse, mutect2, varscan2
- ICE1 | c.6682C>T p.P2228S | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99663953; called by muse, mutect2, varscan2
- ICE1 | c.6683C>T p.P2228L | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99663956; called by muse, mutect2, varscan2
- IDO1 | c.1067T>C p.I356T | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.38); PolyPhen benign (0.011); catalogued as COSV53713040; called by muse, mutect2, varscan2
- IDO2 | c.13C>T p.H5Y | Missense Mutation (SNP) | VAF 52/168 reads (31%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV58423750; called by muse, mutect2, varscan2
- IFT140 | c.320C>T p.T107I | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.101); catalogued as COSV68486035; called by muse, mutect2, varscan2
- IFT172 | c.3980C>T p.P1327L | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.168); catalogued as rs1319050867, COSV53130088; called by muse, mutect2, varscan2
- IGHV1-24 | c.211G>A p.D71N | Missense Mutation (SNP) | VAF 54/200 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs570502677; called by muse, mutect2, varscan2
- IGSF10 | c.6551C>T p.S2184F | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs867454141, COSV56368578; called by muse, varscan2
- IHO1 | c.77G>A p.W26* | Nonsense Mutation (SNP) | VAF 17/44 reads (39%) | catalogued as COSV56506530; called by muse, mutect2, varscan2
- IL10RA | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.027); catalogued as COSV57139796; called by muse, mutect2, varscan2
- IL15 | c.227A>T p.E76V | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); catalogued as COSV56724321; called by muse, mutect2
- IL18RAP | c.1208G>A p.G403E | Missense Mutation (SNP) | VAF 67/145 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.054); catalogued as COSV51823992; called by muse, mutect2, varscan2
- IL1RL2 | c.190C>T p.P64S | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.491); catalogued as COSV51813152, COSV51818326; called by muse, varscan2
- IL1RN | c.10G>A p.A4T (on ENST00000259206 / NM_173841.3; = p.E4K on NM_000577.5) | Missense Mutation (SNP) | VAF 46/102 reads (45%) | PolyPhen benign (0.143); catalogued as COSV52079730; called by muse, mutect2
- IL31RA | c.1249C>T p.Q417* | Nonsense Mutation (SNP) | VAF 9/53 reads (17%) | catalogued as COSV51679466; called by muse, mutect2, varscan2
- ILDR2 | c.740C>T p.P247L | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54828852; called by muse, mutect2, varscan2
- INA | c.1322C>T p.S441F | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as COSV63975640; called by muse, mutect2, varscan2
- INCENP | c.356C>T p.S119F | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.854); catalogued as rs765632070, COSV53913413; called by muse, mutect2, varscan2
- INPP5D | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 48/103 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); catalogued as COSV64035501; called by muse, mutect2, varscan2
- INPP5D | c.3080C>T p.S1027F (on ENST00000445964 / NM_001017915.3; = p.S1026F on NM_005541.5) | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.201); catalogued as COSV64035505; called by muse, mutect2
- INPP5D | c.3221C>T p.P1074L (on ENST00000445964 / NM_001017915.3; = p.P1073L on NM_005541.5) | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as rs747339223, COSV64037208; called by muse, mutect2, varscan2
- INPP5F | c.1363C>T p.R455C | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1189499242, COSV62819797; called by muse, mutect2, varscan2
- INSR | c.1007C>T p.P336L | Missense Mutation (SNP) | VAF 333/647 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.028); catalogued as COSV57158106; called by muse, mutect2, varscan2
- IPO5 | c.3179G>C p.R1060P | Missense Mutation (SNP) | VAF 71/200 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55152236; called by muse, mutect2, varscan2
- IQCH | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.022); catalogued as COSV100246205, COSV60049357; called by muse, mutect2, varscan2
- IRF6 | c.938C>T p.A313V | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65418719; called by muse, mutect2, varscan2
- ITGA1 | c.2605G>A p.G869R | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.716); catalogued as COSV50876634; called by muse, mutect2, varscan2
- ITGA4 | c.1360C>T p.R454W | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs201906563, COSV51998072; called by muse, mutect2, varscan2
- ITGAE | c.1943C>T p.S648F | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs759934531, COSV53989224; called by muse, mutect2
- ITGAE | c.1941G>T p.M647I | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs1486994510, COSV53989604; called by muse, mutect2
- ITGB7 | c.1691C>T p.A564V | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT tolerated (0.89); PolyPhen benign (0.217); catalogued as COSV57237812; called by muse, mutect2, varscan2
- ITGB8 | c.436C>T p.P146S | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781494418, COSV56005209; called by muse, mutect2, varscan2
- ITGB8 | c.914G>A p.G305E | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs750312968, COSV56005227; called by muse, mutect2, varscan2
- ITLN2 | c.272G>A p.W91* | Nonsense Mutation (SNP) | VAF 20/45 reads (44%) | catalogued as COSV63537464; called by muse, mutect2, varscan2
- ITPR1 | c.4303G>A p.E1435K (on ENST00000354582; = p.E1420K on NM_002222.7) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56969968; called by muse, mutect2, varscan2
- ITSN1 | c.4004G>C p.R1335P | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.496); catalogued as COSV67156859; called by muse, varscan2
- IVL | c.71C>T p.P24L | Missense Mutation (SNP) | VAF 39/76 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.078); catalogued as COSV64215570; called by muse, mutect2, varscan2
- IZUMO1R | c.104G>A p.R35K | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT tolerated (0.83); PolyPhen benign (0.005); catalogued as rs1157070175, COSV60622185; called by muse, mutect2, varscan2
- JAG1 | c.3127G>A p.D1043N | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs1278689263, COSV54753771; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- JAKMIP1 | c.1397G>A p.R466K | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.576); catalogued as COSV51522757; called by muse, mutect2, varscan2
- JPH3 | c.1058C>T p.P353L | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV52464478; called by muse, mutect2, varscan2
- KANK4 | c.38G>A p.G13E | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV62985516; called by muse, mutect2, varscan2
- KBTBD8 | c.1670C>T p.S557F | Missense Mutation (SNP) | VAF 44/127 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV55126916; called by muse, mutect2, varscan2
- KCNA1 | c.895G>A p.V299I | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as CM095683, COSV66836433, COSV66836609; called by muse, mutect2, varscan2
- KCNA10 | c.44A>G p.N15S | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as COSV100871404; called by muse, mutect2, varscan2
- KCNA3 | c.1013C>T p.P338L | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63901029; called by muse, mutect2, varscan2
- KCNG4 | c.977G>A p.S326N | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (0.98); PolyPhen benign (0.006); catalogued as COSV57582733; called by muse, mutect2, varscan2
- KCNG4 | c.217C>T p.P73S | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.994); catalogued as rs909632099, COSV57582741; called by muse, mutect2, varscan2
- KCNH3 | c.2741G>A p.R914K | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs761142096, COSV57789742; called by muse, mutect2, varscan2
- KCNH5 | c.1858G>A p.E620K | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.673); catalogued as COSV59751934; called by muse, mutect2, varscan2
- KCNH7 | c.2536G>A p.D846N | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as COSV59785513; called by muse, mutect2, varscan2
- KCNH7 | c.1303G>A p.D435N | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.137); catalogued as COSV59786169; called by muse, mutect2, varscan2
- KCNIP1 | c.115G>A p.E39K (on ENST00000411494 / NM_001034837.3; = p.E28K on NM_014592.4) | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.303); catalogued as COSV61080686; called by muse, mutect2, varscan2
- KCNK6 | c.437C>T p.S146L | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV54578965; called by muse, mutect2, varscan2
- KCNT2 | c.513G>A p.W171* | Nonsense Mutation (SNP) | VAF 16/45 reads (36%) | catalogued as COSV54065202; called by muse, mutect2, varscan2
- KCTD16 | c.1070C>T p.S357L | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as COSV72576821; called by muse, mutect2, varscan2
- KDR | c.3686G>A p.R1229Q | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.943); catalogued as rs776015468, COSV55758511; called by muse, mutect2, varscan2
- KEL | c.413C>T p.S138F | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT tolerated (0.79); PolyPhen benign (0.071); catalogued as COSV62333436; called by muse, mutect2, varscan2
- KHDC3L | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 65/89 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs1254478088, COSV64862954; called by muse, mutect2, varscan2
- KIAA1109 | c.9569G>A p.R3190Q | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV52663090; called by muse, mutect2, varscan2
- KIF1A | c.2717C>T p.S906L | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs1553630819, COSV57483181; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIF1B | c.3640C>T p.Q1214* (on ENST00000377086 / NM_001365952.1; = p.Q1168* on NM_015074.3) | Nonsense Mutation (SNP) | VAF 8/30 reads (27%) | catalogued as COSV55803879; called by muse, mutect2, varscan2
- KIF2B | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 50/138 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); catalogued as rs1479558414, COSV52127285; called by muse, mutect2, varscan2
- KIR2DL3 | c.515C>T p.S172F | Missense Mutation (SNP) | VAF 31/176 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); catalogued as COSV100667607; called by muse, mutect2, varscan2
- KLHDC8A | c.863A>G p.N288S | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.608); catalogued as COSV65678243; called by muse, mutect2
- KLHL4 | c.679G>A p.G227R | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as rs1448293439, COSV64139303; called by muse, mutect2, varscan2
- KNG1 | c.1279C>T p.R427C | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs760597319, COSV53976170, COSV99405842; called by muse, mutect2, varscan2
- KRT15 | c.172G>A p.G58R | Missense Mutation (SNP) | VAF 58/120 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs751231336, COSV54178090; called by muse, mutect2, varscan2
- KRT74 | c.248G>A p.G83E | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.089); catalogued as rs777665234, COSV59770605; called by muse, mutect2, varscan2
- KRTAP15-1 | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.149); catalogued as COSV61877049; called by muse, mutect2
- KSR2 | c.570G>A p.W190* | Nonsense Mutation (SNP) | VAF 15/57 reads (26%) | catalogued as COSV60366910; called by muse, mutect2, varscan2
- L1CAM | c.2050C>T p.H684Y | Missense Mutation (SNP) | VAF 115/154 reads (75%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV62826953; called by muse, mutect2, varscan2
- LAMA3 | c.7339G>A p.D2447N (on ENST00000313654 / NM_198129.4; = p.D838N on NM_000227.6) | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0.209); catalogued as COSV99334063; called by muse, mutect2, varscan2
- LAMB4 | c.1376C>T p.P459L | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.83); catalogued as COSV52713817; called by muse, mutect2, varscan2
- LDHAL6B | c.1037A>G p.E346G | Missense Mutation (SNP) | VAF 46/130 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.326); catalogued as COSV55682765; called by muse, mutect2, varscan2
- LEPR | c.2156C>T p.S719L | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60747895; called by muse, mutect2, varscan2
- LGR6 | c.82C>T p.P28S | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT tolerated (0.5); PolyPhen benign (0.031); catalogued as COSV66154797; called by muse, mutect2
- LGSN | c.1399G>A p.E467K | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.021); catalogued as COSV65726303; called by muse, mutect2, varscan2
- LHX8 | c.782G>A p.R261K | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.74); PolyPhen benign (0.125); catalogued as COSV53954502, COSV53960616; called by muse, mutect2, varscan2
- LHX8 | c.875C>T p.T292I | Missense Mutation (SNP) | VAF 50/202 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.034); catalogued as rs1254384903, COSV53954512; called by muse, mutect2, varscan2
- LILRB3 | c.355G>A p.G119R | Missense Mutation (SNP) | VAF 37/177 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs572921271; called by muse, varscan2
- LMO2 | c.71C>T p.P24L (on ENST00000395833 / NM_001142315.2; = p.P93L on NM_005574.4) | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as COSV57645505; called by muse, mutect2, varscan2
- LMO7 | c.2201G>A p.R734Q (on ENST00000357063; = p.R415Q on NM_005358.5) | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372334697, COSV58542054; called by muse, mutect2, varscan2
- LMTK3 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54309825; called by muse, mutect2, varscan2
- LNPK | c.1195G>A p.E399K | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV55822518; called by muse, mutect2, varscan2
- LPA | c.4031A>C p.E1344A | Missense Mutation (SNP) | VAF 40/72 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV60297341, COSV60301034; called by muse, mutect2, varscan2
- LRGUK | c.2210C>T p.S737F | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV53634336; called by muse, mutect2, varscan2
- LRIG3 | c.2833C>T p.H945Y | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.085); catalogued as COSV57861068; called by muse, mutect2, varscan2
- LRP1B | c.11012G>A p.G3671E | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.444); catalogued as rs762783929, COSV67189215, COSV67278652; called by muse, mutect2, varscan2
- LRP1B | c.10033G>A p.G3345R | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT tolerated (0.51); PolyPhen benign (0.19); catalogued as COSV101257783, COSV67189219, COSV67231331; called by muse, mutect2, varscan2
- LRP2 | c.10457G>A p.G3486E | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55541855; called by muse, mutect2, varscan2
- LRP2 | c.6004C>T p.P2002S | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated (0.58); PolyPhen benign (0.014); catalogued as rs1335599351, COSV55541867; called by muse, mutect2, varscan2
- LRRC2 | c.710C>T p.S237L | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.038); catalogued as rs775968286, COSV56125007; called by muse, mutect2, varscan2
- LRRC27 | c.529C>T p.L177F | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59807304; called by muse, mutect2, varscan2
- LRRC52 | c.365C>T p.S122L | Missense Mutation (SNP) | VAF 91/191 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.121); catalogued as rs201605916, COSV54231370; called by muse, mutect2, varscan2
- LRRC7 | c.4279C>T p.R1427C (on ENST00000651989 / NM_001370785.2; = p.R1347C on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs752431101, COSV50413525; called by muse, mutect2, varscan2
- LRRFIP2 | c.253T>A p.S85T | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.818); catalogued as COSV60866314; called by muse, mutect2, varscan2
- LRRIQ4 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.373); catalogued as COSV61618677; called by muse, mutect2, varscan2
- LRRN1 | c.2122G>A p.D708N | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.263); catalogued as rs147112564; called by muse, mutect2, varscan2
- LRRN2 | c.728C>T p.S243F | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV65783252; called by muse, mutect2, varscan2
- LRRTM4 | c.1447G>A p.E483K | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV69139066; called by muse, mutect2, varscan2
- LTBP1 | c.1375C>T p.H459Y (on ENST00000404816 / NM_206943.4; = p.H133Y on NM_000627.4) | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs774476886, COSV63180575; called by muse, mutect2, varscan2
- LUC7L | c.898C>T p.R300W | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs747798961, COSV53456929; called by muse, mutect2, varscan2
- LVRN | c.1486G>A p.E496K | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.179); catalogued as rs140991083, COSV63496114; called by muse, mutect2, varscan2
- LVRN | c.2302C>T p.R768C | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs369575731; called by muse, mutect2, varscan2
- LYG2 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV60715256; called by muse, mutect2, varscan2
- MACF1 | c.21472C>T p.R7158C (on ENST00000372915; = p.R5203C on NM_012090.5) | Missense Mutation (SNP) | VAF 12/55 reads (22%) | catalogued as COSV57128977; called by muse, mutect2, varscan2
- MAGEA4 | c.467C>T p.S156F | Missense Mutation (SNP) | VAF 62/80 reads (78%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.455); catalogued as COSV52340318; called by muse, mutect2, varscan2
- MAN1B1 | c.833C>T p.S278F | Missense Mutation (SNP) | VAF 44/90 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65377646; called by muse, mutect2, varscan2
- MAOB | c.1075G>A p.E359K | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT tolerated (0.08); PolyPhen benign (0.275); catalogued as COSV65204330; called by muse, mutect2, varscan2
- MAOB | c.1007A>G p.N336S | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1480425646, COSV65204338; called by muse, mutect2, varscan2
- MAP3K19 | c.1669G>A p.E557K | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.03); catalogued as COSV59636798; called by muse, mutect2, varscan2
- MAP3K19 | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as COSV59636805; called by muse, mutect2, varscan2
- MAPK4 | c.1753G>A p.E585K | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.187); catalogued as rs7506742, COSV68541198; called by muse, mutect2, varscan2
- MARCO | c.829G>A p.G277R | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59051986; called by muse, mutect2, varscan2
- MARK4 | c.1942C>T p.Q648* (on ENST00000262891 / NM_001199867.2; = p.I674= on NM_031417.4) | Nonsense Mutation (SNP) | VAF 135/292 reads (46%) | catalogued as COSV53461712; called by muse, mutect2, varscan2
- MAST4 | c.1054C>T p.R352C (on ENST00000403625 / NM_001164664.2; = p.R163C on NM_015183.3) | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1407792110, COSV99843139; called by muse, mutect2, varscan2
- MCCC2 | c.497C>T p.P166L | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.997); catalogued as COSV60152911; called by muse, mutect2, varscan2
- MCM3AP | c.5590T>A p.C1864S | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV52436521; called by muse, mutect2, varscan2
- MDGA2 | c.1727G>A p.R576K (on ENST00000399232 / NM_001113498.2; = p.R278K on NM_182830.4) | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as COSV62079963; called by muse, varscan2
- MEF2A | c.580C>T p.P194S (on ENST00000557942 / NM_001319206.2; = p.P196S on NM_005587.4 and 8 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 54/181 reads (30%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as COSV57530169; called by muse, mutect2, varscan2
- MEGF8 | c.5260G>A p.E1754K (on ENST00000251268 / NM_001271938.2; = p.E1687K on NM_001410.3) | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0.014); catalogued as COSV52075942; called by muse, mutect2
- MEIS1 | c.302C>T p.P101L | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs959662082, COSV55483692; called by muse, mutect2, varscan2
- MEP1A | c.389C>T p.S130F | Missense Mutation (SNP) | VAF 41/84 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57918121; called by muse, mutect2, varscan2
- MEPE | c.806G>A p.G269E | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.65); catalogued as COSV63071884; called by muse, mutect2, varscan2
- MFN1 | c.1567C>T p.R523C | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs763462241, COSV54938140; called by muse, mutect2, varscan2
- MGLL | c.826C>T p.P276S (on ENST00000398104 / NM_001003794.2; = p.P286S on NM_007283.6) | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); catalogued as COSV54022647; called by muse, mutect2, varscan2
- MIP | c.323C>T p.T108I | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.926); catalogued as rs760722691, COSV57509159, COSV57510065; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MISP | c.1502G>A p.W501* | Nonsense Mutation (SNP) | VAF 38/64 reads (59%) | catalogued as COSV53118905; called by muse, mutect2, varscan2
- MKLN1 | c.2009C>T p.S670L | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.05); catalogued as COSV61760040; called by muse, mutect2, varscan2
- MLIP | c.1238C>T p.P413L | Missense Mutation (SNP) | VAF 56/251 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.859); catalogued as rs773508128, COSV51429592; called by muse, mutect2, varscan2
- MLLT1 | c.925C>T p.R309W | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs151080263; called by muse, mutect2
- MMP13 | c.991C>T p.P331S | Missense Mutation (SNP) | VAF 30/47 reads (64%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV52823154; called by muse, mutect2, varscan2
- MOB2 | c.206G>A p.S69N | Missense Mutation (SNP) | VAF 45/169 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV57317954, COSV57319628; called by muse, mutect2, varscan2
- MOGAT1 | c.320G>A p.G107E | Missense Mutation (SNP) | VAF 26/42 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101490098, COSV71479806; called by muse, mutect2, varscan2
- MOGAT2 | c.412C>T p.H138Y | Missense Mutation (SNP) | VAF 59/153 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs368100933; called by muse, mutect2, varscan2
- MPL | c.845G>A p.G282E | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs1307494831, COSV65244120; called by muse, mutect2, varscan2
- MPP2 | c.983C>T p.P328L (on ENST00000461854 / NM_001278372.2; = p.P304L on NM_005374.5) | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.028); catalogued as rs1314995391, COSV52233140; called by muse, mutect2, varscan2
- MRGPRE | c.638G>A p.R213Q | Missense Mutation (SNP) | VAF 11/12 reads (92%) | SIFT tolerated (0.54); PolyPhen benign (0.164); catalogued as rs564898039, COSV67745536; called by muse, mutect2, varscan2
- MROH2B | c.3185A>T p.Q1062L | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV68181227; called by muse, mutect2, varscan2
- MROH2B | c.3043G>A p.G1015S | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.144); catalogued as rs1211364496, COSV68181233, COSV68191170; called by muse, mutect2, varscan2
- MROH8 | c.1070G>A p.G357E | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54117459, COSV99456615; called by muse, mutect2, varscan2
- MRPL9 | c.557C>T p.P186L | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as COSV100162374; called by muse, mutect2, varscan2
- MS4A2 | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs913418854, COSV99627072; called by muse, mutect2, varscan2
- MS4A6A | c.14C>T p.P5L | Missense Mutation (SNP) | VAF 49/120 reads (41%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.923); catalogued as COSV60616883; called by muse, mutect2, varscan2
- MTMR3 | c.91C>T p.Q31* | Nonsense Mutation (SNP) | VAF 29/49 reads (59%) | catalogued as COSV60301977; called by muse, mutect2, varscan2
- MTOR | c.1639C>T p.L547F | Missense Mutation (SNP) | VAF 52/102 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63868635; called by muse, mutect2, varscan2
- MTUS2 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.272); catalogued as rs779634476, COSV70913950, COSV70914558; called by muse, mutect2, varscan2
- MUC16 | c.41416G>A p.E13806K | Missense Mutation (SNP) | VAF 69/152 reads (45%) | SIFT tolerated, low confidence (0.21); PolyPhen probably damaging (0.915); catalogued as COSV66689955; called by muse, mutect2, varscan2
- MUC16 | c.35605C>T p.L11869F | Missense Mutation (SNP) | VAF 25/191 reads (13%) | SIFT tolerated, low confidence (0.69); PolyPhen possibly damaging (0.534); catalogued as COSV67446830; called by muse, mutect2, varscan2
- MUC16 | c.35359C>T p.P11787S | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.279); catalogued as COSV67446836, COSV67493766; called by muse, mutect2, varscan2
- MUC16 | c.27068C>T p.P9023L | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.023); catalogued as COSV67446839; called by muse, mutect2, varscan2
- MUC16 | c.26542G>A p.E8848K | Missense Mutation (SNP) | VAF 93/148 reads (63%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.005); catalogued as rs758682809, COSV67446748, COSV67446844; called by muse, mutect2, varscan2
- MUC16 | c.23225C>T p.S7742L | Missense Mutation (SNP) | VAF 29/180 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.047); catalogued as COSV67446858; called by muse, mutect2, varscan2
- MUC16 | c.11792G>A p.R3931K | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.047); catalogued as COSV67446861, COSV67461086; called by muse, mutect2, varscan2
- MUC16 | c.6885G>A p.W2295* | Nonsense Mutation (SNP) | VAF 15/33 reads (45%) | catalogued as COSV67446866; called by muse, mutect2, varscan2
- MUC16 | c.2078G>A p.G693E | Missense Mutation (SNP) | VAF 48/81 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.151); catalogued as COSV67446876; called by muse, mutect2, varscan2
- MUC16 | c.218G>A p.G73E | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.041); catalogued as COSV67446881; called by muse, mutect2, varscan2
- MUC3A | c.8111C>T p.S2704F | Missense Mutation (SNP) | VAF 87/754 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs1189331563, COSV60210914; called by muse, mutect2, varscan2
- MUC4 | c.15859G>A p.D5287N (on ENST00000463781 / NM_018406.7; = p.D1051N on NM_004532.6) | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.267); catalogued as rs765029904, COSV57767328; called by muse, mutect2, varscan2
- MUCL3 | c.1471G>A p.D491N (on ENST00000304311; = p.D1367N on NM_080870.4) | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.422); catalogued as COSV58515998; called by muse, mutect2, varscan2
- MVP | c.935C>T p.P312L | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); catalogued as rs1318060864, COSV62421412; called by muse, mutect2, varscan2
- MXRA5 | c.6887G>A p.G2296E | Missense Mutation (SNP) | VAF 49/63 reads (78%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV54224655; called by muse, mutect2, varscan2
- MYBL1 | c.1613G>A p.G538E | Missense Mutation (SNP) | VAF 43/139 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV72918721; called by muse, mutect2, varscan2
- MYH1 | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as rs987175366, COSV56844003; called by muse, mutect2, varscan2
- MYH15 | c.2366G>A p.R789K | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV56304806; called by muse, varscan2
- MYH15 | c.2338G>A p.G780R | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.169); catalogued as COSV56304816; called by muse, varscan2
- MYH4 | c.929C>T p.P310L | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781091968, COSV55112713; called by muse, mutect2, varscan2
- MYH8 | c.3203C>T p.S1068F | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); catalogued as rs1297364390, COSV67960189; called by muse, mutect2, varscan2
- MYL1 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 84/190 reads (44%) | SIFT tolerated (0.26); PolyPhen benign (0.02); catalogued as COSV61681269; called by muse, mutect2, varscan2
- MYLK | c.2062G>A p.E688K | Missense Mutation (SNP) | VAF 57/136 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV60605240; called by muse, mutect2, varscan2
- MYO10 | c.5567C>T p.S1856F | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as COSV57017119; called by muse, mutect2, varscan2
- MYO15A | c.1540G>T p.E514* | Nonsense Mutation (SNP) | VAF 4/32 reads (13%) | catalogued as COSV52752203; called by muse, mutect2, varscan2
- MYO1G | c.1654G>A p.D552N | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.08); catalogued as COSV51853218; called by muse, mutect2, varscan2
- MYO5C | c.5149C>T p.P1717S | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1190070342, COSV55897911; called by muse, mutect2, varscan2
- MYOM3 | c.3793G>A p.D1265N | Missense Mutation (SNP) | VAF 44/160 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.332); catalogued as rs895877283, COSV58390021; called by muse, mutect2, varscan2
- MYPN | c.962G>A p.G321E | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs866874434, COSV62731772; called by muse, mutect2, varscan2
- NAA16 | c.1239G>A p.M413I | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1401162861, COSV65064278; called by muse, mutect2, varscan2
- NAXD | c.1130G>A p.R377Q | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.784); catalogued as rs761316228, COSV57284166; called by muse, mutect2, varscan2
- NBEA | c.3422A>G p.N1141S | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); catalogued as COSV59762111; called by muse, mutect2, varscan2
- NCAM1 | c.67G>A p.D23N | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV57511041; called by muse, mutect2, varscan2
- NCKAP5 | c.2429C>T p.S810L | Missense Mutation (SNP) | VAF 50/249 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as COSV58428882; called by muse, mutect2, varscan2
- NCKAP5 | c.359G>A p.R120Q | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs775385683, COSV100489265, COSV58428895; called by muse, mutect2, varscan2
- NCOA3 | c.3637C>T p.Q1213* | Nonsense Mutation (SNP) | VAF 12/43 reads (28%) | catalogued as COSV59065874; called by muse, mutect2, varscan2
- NDNF | c.428C>T p.S143F | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV65632670; called by muse, mutect2, varscan2
- NDST3 | c.181C>T p.Q61* | Nonsense Mutation (SNP) | VAF 33/79 reads (42%) | catalogued as COSV56613488; called by muse, mutect2, varscan2
- NDST4 | c.2463A>T p.K821N | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.611); catalogued as COSV52109799; called by muse, mutect2, varscan2
- NDST4 | c.646C>T p.P216S | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.562); catalogued as rs776332088, COSV52109537, COSV52125865; called by muse, mutect2, varscan2
- NEB | c.8633C>T p.P2878L | Missense Mutation (SNP) | VAF 64/153 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50816364; called by muse, mutect2, varscan2
- NEBL | c.1546G>A p.E516K | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.63); PolyPhen benign (0.017); catalogued as rs45461595; ClinVar: uncertain significance; called by muse, varscan2
- NEFM | c.685G>A p.D229N | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV55330531; called by muse, mutect2, varscan2
- NET1 | c.1686G>A p.M562I (on ENST00000355029 / NM_001047160.3; = p.M508I on NM_005863.5) | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as COSV100742209, COSV61790856; called by muse, mutect2, varscan2
- NEURL1 | c.1721C>T p.S574F | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.365); catalogued as COSV63507930; called by muse, mutect2
- NEXMIF | c.2984C>T p.S995L | Missense Mutation (SNP) | VAF 20/24 reads (83%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as COSV50022228, COSV99281892; called by muse, mutect2, varscan2
- NEXMIF | c.1972G>A p.D658N | Missense Mutation (SNP) | VAF 10/12 reads (83%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.526); catalogued as COSV50022240; called by muse, mutect2, varscan2
- NEXMIF | c.462G>T p.K154N | Missense Mutation (SNP) | VAF 46/60 reads (77%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.73); catalogued as COSV50022250; called by muse, mutect2, varscan2
- NF1 | c.4875C>A p.Y1625* (on ENST00000358273 / NM_001042492.3; = p.Y1604* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 46/89 reads (52%) | catalogued as CM1311478, CM143419, COSV55985556, COSV55987204; called by muse, mutect2, varscan2
- NFATC1 | c.1367G>A p.G456E | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53695523; called by muse, mutect2, varscan2
- NID2 | c.1288C>T p.P430S | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.009); catalogued as COSV53493294; called by muse, mutect2, varscan2
- NIPAL2 | c.904C>T p.L302F | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.64); PolyPhen benign (0.007); catalogued as rs775422243, COSV100358657, COSV57838184; called by muse, mutect2, varscan2
- NKX3-1 | c.542G>A p.R181Q | Missense Mutation (SNP) | VAF 63/202 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1200957711, COSV66511762; called by muse, mutect2, varscan2
- NLRP13 | c.1330G>A p.D444N | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT tolerated (0.36); PolyPhen benign (0.04); catalogued as rs150988752; called by muse, mutect2, varscan2
- NLRP5 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs373401163; called by muse, mutect2, varscan2
- NLRP5 | c.399G>A p.M133I | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV101173858, COSV66762248; called by muse, mutect2, varscan2
- NLRP5 | c.1810G>A p.E604K | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.03); catalogued as rs1011984538, COSV66762254; called by muse, mutect2, varscan2
- NMS | c.265C>T p.P89S | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT tolerated (0.45); PolyPhen benign (0.022); catalogued as COSV65258334; called by muse, mutect2, varscan2
- NMS | c.406C>T p.L136F | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.359); catalogued as COSV65258339; called by muse, mutect2, varscan2
- NOL4 | c.1289C>T p.S430F | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52339350; called by muse, mutect2, varscan2
- NOS1 | c.3406-1G>A p.X1136_splice | Splice Site (SNP) | VAF 20/45 reads (44%) | catalogued as rs1203304700, COSV57607278; called by muse, mutect2, varscan2
- NOS1 | c.2630G>A p.G877E | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as COSV57607290; called by muse, mutect2, varscan2
- NOS1 | c.1837G>A p.E613K | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.843); catalogued as COSV57607304, COSV57608051, COSV57622280; called by muse, mutect2, varscan2
- NOTCH2 | c.2166C>G p.N722K | Missense Mutation (SNP) | VAF 379/862 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.136); catalogued as COSV56682587, COSV99864043; called by muse, mutect2, varscan2
- NOTCH4 | c.3442G>A p.E1148K | Missense Mutation (SNP) | VAF 124/439 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0.164); catalogued as COSV66678894; called by muse, mutect2, varscan2
- NOX1 | c.286C>T p.H96Y | Missense Mutation (SNP) | VAF 101/135 reads (75%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as COSV54193478; called by muse, mutect2, varscan2
- NPC1L1 | c.2608G>A p.G870R | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1431424872, COSV56922676; called by muse, mutect2, varscan2
- NPSR1 | c.401C>T p.A134V | Missense Mutation (SNP) | VAF 44/104 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62196696; called by muse, mutect2
- NPTX1 | c.988C>T p.Q330* | Nonsense Mutation (SNP) | VAF 21/51 reads (41%) | catalogued as COSV60774353; called by muse, mutect2, varscan2
- NPTXR | c.1031G>A p.G344E | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as COSV60727746; called by muse, mutect2, varscan2
- NR5A2 | c.260C>T p.P87L (on ENST00000367362 / NM_205860.3; = p.P41L on NM_003822.5) | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.765); catalogued as COSV52645406; called by muse, mutect2, varscan2
- NRK | c.61C>T p.P21S | Missense Mutation (SNP) | VAF 27/45 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV54590370; called by muse, mutect2, varscan2
- NRXN3 | c.1477G>A p.E493K (on ENST00000335750 / NM_001330195.2; = p.E120K on NM_004796.6) | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT tolerated (0.68); PolyPhen benign (0.178); catalogued as rs148371115, COSV59716448; called by muse, mutect2
- NSUN7 | c.919G>A p.V307I | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.47); PolyPhen benign (0.406); catalogued as COSV57272598; called by muse, mutect2, varscan2
- NTRK3 | c.1729C>T p.P577S | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.18); catalogued as COSV62296395; called by muse, mutect2, varscan2
- NTRK3 | c.1108C>A p.H370N | Missense Mutation (SNP) | VAF 45/154 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58110687; called by muse, mutect2, varscan2
- NUP205 | c.4987C>T p.Q1663* | Nonsense Mutation (SNP) | VAF 31/74 reads (42%) | catalogued as COSV53655288; called by muse, mutect2, varscan2
- NUP210L | c.5158G>A p.D1720N | Missense Mutation (SNP) | VAF 96/218 reads (44%) | SIFT tolerated (0.36); PolyPhen benign (0.156); catalogued as COSV55142116; called by muse, mutect2, varscan2
- NUTM1 | c.2500G>A p.D834N | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV59215838; called by muse, mutect2, varscan2
- NWD1 | c.1207C>T p.P403S | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.055); catalogued as COSV60337976; called by muse, mutect2
- OCA2 | c.458C>T p.S153F | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.316); catalogued as COSV62339165; called by muse, mutect2, varscan2
- OGDHL | c.2583G>A p.M861I | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.059); catalogued as COSV65101062; called by muse, mutect2, varscan2
- OPRK1 | c.1052G>A p.R351K | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV55568453; called by muse, mutect2, varscan2
- OR10G9 | c.668C>T p.S223F | Missense Mutation (SNP) | VAF 50/75 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV66685778; called by muse, mutect2, varscan2
- OR10J1 | c.926C>T p.S309F | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs373330432, COSV101419901, COSV71128120; called by muse, mutect2, varscan2
- OR10P1 | c.692C>T p.S231F | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV59006736; called by muse, mutect2, varscan2
- OR10V1 | c.632C>T p.P211L | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55695123; called by muse, mutect2, varscan2
- OR10X1 | c.930G>A p.M310I | Missense Mutation (SNP) | VAF 49/110 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV100936633, COSV63766869; called by muse, varscan2
- OR13G1 | c.483G>A p.M161I | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as COSV62943429; called by muse, mutect2, varscan2
- OR1A2 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 47/115 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV67936107; called by muse, mutect2, varscan2
- OR1B1 | c.746C>T p.S249F | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1165334474, COSV59171075; called by muse, mutect2, varscan2
- OR1D2 | c.856C>T p.P286S | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV58921070; called by muse, mutect2, varscan2
- OR1D5 | c.671C>T p.T224I | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.428); catalogued as COSV73859480; called by muse, mutect2, varscan2
- OR1J2 | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 48/117 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.847); catalogued as COSV58943769; called by muse, mutect2, varscan2
- OR1N2 | c.5G>A p.G2E | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV65460229; called by muse, mutect2, varscan2
- OR2A5 | c.136G>A p.G46R | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.878); catalogued as rs751161982, COSV68738532; called by muse, mutect2, varscan2
- OR2M2 | c.467G>A p.G156E | Missense Mutation (SNP) | VAF 60/251 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); catalogued as COSV62897862; called by muse, mutect2, varscan2
- OR2M3 | c.467G>A p.G156E | Missense Mutation (SNP) | VAF 64/161 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.253); catalogued as COSV71758873; called by muse, mutect2, varscan2
- OR2M3 | c.548C>T p.S183F | Missense Mutation (SNP) | VAF 84/216 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as COSV71758836; called by muse, mutect2, varscan2
- OR2T1 | c.937G>A p.V313M | Missense Mutation (SNP) | VAF 32/159 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.04); catalogued as rs763683847, COSV63541298; called by muse, mutect2, varscan2
- OR2T11 | c.850C>T p.P284S | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58184811; called by muse, mutect2, varscan2
- OR3A1 | c.857C>T p.P286L | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs780106189, COSV60162539; called by muse, mutect2, varscan2
- OR4A47 | c.449G>A p.G150E | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.94); catalogued as rs267602922, COSV71444847; called by muse, mutect2, varscan2
- OR4B1 | c.605G>A p.G202E | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV58882054; called by muse, mutect2, varscan2
- OR4C46 | c.644C>T p.S215F | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.833); catalogued as COSV60218429; called by muse, mutect2
- OR4K13 | c.440C>T p.S147F | Missense Mutation (SNP) | VAF 23/158 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV59859036; called by muse, mutect2, varscan2
- OR4K2 | c.523G>A p.D175N | Missense Mutation (SNP) | VAF 60/683 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.362); catalogued as rs748394926, COSV53848232; called by muse, mutect2
- OR4K5 | c.834C>G p.F278L | Missense Mutation (SNP) | VAF 41/220 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.038); catalogued as COSV60002395; called by muse, mutect2, varscan2
- OR4N2 | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 92/426 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs866280852, COSV60050102; called by muse, mutect2, varscan2
- OR4N2 | c.334G>A p.G112R | Missense Mutation (SNP) | VAF 30/273 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.09); catalogued as COSV60050111; called by muse, mutect2, varscan2
- OR51A2 | c.731C>T p.S244L | Missense Mutation (SNP) | VAF 34/154 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV66748142; called by muse, varscan2
- OR51A4 | c.731C>T p.S244L | Missense Mutation (SNP) | VAF 22/166 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV100985249, COSV66749071; called by muse, mutect2
- OR51B5 | c.830C>T p.A277V | Missense Mutation (SNP) | VAF 43/75 reads (57%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV56175038; called by muse, mutect2, varscan2
- OR51F1 | c.857C>T p.A286V | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs1163818207, COSV58578894; called by muse, mutect2
- OR51G2 | c.488C>T p.P163L | Missense Mutation (SNP) | VAF 39/61 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58991918; called by muse, varscan2
- OR51L1 | c.221G>A p.G74E | Missense Mutation (SNP) | VAF 51/182 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58623954; called by muse, mutect2, varscan2
- OR5M3 | c.215C>T p.S72F | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56565771; called by muse, mutect2, varscan2
- OR5T2 | c.841G>A p.G281R | Missense Mutation (SNP) | VAF 50/129 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57587922; called by muse, mutect2, varscan2
- OR6B3 | c.443C>T p.S148F | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866150175, COSV100096989; called by muse, mutect2, varscan2
- OR6C1 | c.811G>A p.G271R | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.25); catalogued as rs1319739282, COSV65572636; called by muse, mutect2, varscan2
- OR6C68 | c.925C>T p.R309C | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.101); catalogued as rs182070849, COSV65562794; called by muse, mutect2, varscan2
- OR6C75 | c.257G>A p.G86E | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.012); catalogued as rs267603564, COSV58551148; called by muse, mutect2, varscan2
- OR6S1 | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as rs377094348; called by muse, mutect2, varscan2
- OR7D2 | c.322C>T p.P108S | Missense Mutation (SNP) | VAF 36/186 reads (19%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.001); catalogued as COSV60138881; called by muse, mutect2, varscan2
- OR7E24 | c.940G>A p.D314N | Missense Mutation (SNP) | VAF 40/66 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0.132); catalogued as COSV71702129; called by muse, mutect2, varscan2
- OR8B8 | c.26T>G p.V9G | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as COSV60143794, COSV60144432; called by muse, varscan2
- OR9G1 | c.119G>A p.G40E | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs762148890, COSV56448362; called by muse, mutect2, varscan2
- OR9Q2 | c.135G>A p.M45I | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.275); catalogued as rs866477329, COSV61111428; called by muse, mutect2, varscan2
- OTOF | c.1927G>A p.E643K | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs200864338, COSV55496524; called by muse, mutect2, varscan2
- OVCH1 | c.2108G>A p.W703* | Nonsense Mutation (SNP) | VAF 23/37 reads (62%) | catalogued as rs753442528, COSV58959865; called by muse, mutect2, varscan2
- P2RY12 | c.268G>A p.G90R | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.038); catalogued as rs1560046688, COSV56369373; called by muse, mutect2, varscan2
- PAK5 | c.1256C>T p.S419F | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as COSV62019935; called by muse, mutect2, varscan2
- PAMR1 | c.1078C>T p.L360F (on ENST00000619888 / NM_001001991.3; = p.L377F on NM_015430.4) | Missense Mutation (SNP) | VAF 37/168 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs777312333, COSV53509494, COSV53509816; called by muse, mutect2, varscan2
- PANK3 | c.35C>T p.P12L | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99496197; called by muse, mutect2, varscan2
- PANK3 | c.34C>T p.P12S | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99496198; called by muse, mutect2, varscan2
- PARP15 | c.1607G>A p.S536N (on ENST00000464300 / NM_001113523.3; = p.S302N on NM_152615.2) | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.914); catalogued as rs756878221, COSV59971425, COSV59971561; called by muse, mutect2, varscan2
- PCDH11X | c.1213C>T p.P405S | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100009021; called by muse, mutect2, varscan2
- PCDH11Y | c.1309C>T p.P437S (on ENST00000400457 / NM_032973.2; = p.P426S on NM_032971.3) | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53074624; called by muse, mutect2, varscan2
- PCDH17 | c.2700T>G p.S900R | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64971928; called by muse, mutect2, varscan2
- PCDH17 | c.2849C>T p.S950F | Missense Mutation (SNP) | VAF 35/64 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64971932, COSV64977758; called by muse, mutect2, varscan2
- PCDHA4 | c.1862C>T p.P621L | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.055); catalogued as rs782208317, COSV63539124; called by muse, mutect2, varscan2
- PCDHAC2 | c.1286G>A p.R429Q | Missense Mutation (SNP) | VAF 59/159 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs990784546, COSV53838145; called by muse, mutect2, varscan2
- PCDHB1 | c.298G>A p.D100N | Missense Mutation (SNP) | VAF 51/125 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV104404052, COSV60629574; called by muse, varscan2
- PCDHB2 | c.176G>A p.G59E | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.007); catalogued as COSV52029472; called by muse, mutect2, varscan2
- PCDHB3 | c.1466C>T p.S489L | Missense Mutation (SNP) | VAF 46/169 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.927); catalogued as COSV50564466; called by muse, mutect2, varscan2
- PCDHB9 | c.2254G>A p.E752K | Missense Mutation (SNP) | VAF 110/283 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.037); catalogued as COSV53375579, COSV53380716; called by muse, mutect2, varscan2
- PCDHGA1 | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.009); catalogued as rs898742572, COSV65294827; called by muse, mutect2, varscan2
- PCDHGB1 | c.587C>T p.P196L | Missense Mutation (SNP) | VAF 47/157 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.029); catalogued as rs774892780, COSV53903661; called by muse, varscan2
- PCLO | c.13885C>T p.Q4629* | Nonsense Mutation (SNP) | VAF 7/28 reads (25%) | catalogued as COSV61617326, COSV61635151; called by muse, mutect2, varscan2
- PCLO | c.11488G>A p.D3830N | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.447); catalogued as COSV61617334; called by muse, mutect2, varscan2
- PCLO | c.9937C>T p.R3313W | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs758970673, COSV61617340; called by muse, varscan2
- PCLO | c.9850G>A p.E3284K | Missense Mutation (SNP) | VAF 56/141 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61617351; called by muse, varscan2
- PCLO | c.8039C>T p.S2680L | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.642); catalogued as rs1191184226, COSV61617365; called by muse, mutect2, varscan2
- PCNX2 | c.950C>T p.T317I | Missense Mutation (SNP) | VAF 27/139 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.617); catalogued as rs1316214735, COSV50783060; called by muse, mutect2, varscan2
- PCP4L1 | c.173G>A p.R58Q | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs767831354, COSV73440594; called by muse, mutect2
- PDC | c.416A>C p.H139P | Missense Mutation (SNP) | VAF 40/81 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV60853936; called by muse, mutect2, varscan2
- PDE1A | c.355C>T p.R119W | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs770985972, COSV59515206; called by muse, mutect2, varscan2
- PDE8B | c.517C>T p.L173F | Missense Mutation (SNP) | VAF 154/501 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.961); catalogued as COSV53732551, COSV99367542; called by muse, mutect2, varscan2
- PDGFRA | c.1647G>A p.W549* | Nonsense Mutation (SNP) | VAF 14/109 reads (13%) | catalogued as rs747156883, COSV57265043; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PDLIM5 | c.1630C>T p.P544S | Missense Mutation (SNP) | VAF 42/107 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV58745335; called by muse, mutect2, varscan2
- PDS5A | c.1942G>A p.E648K | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0.011); catalogued as COSV57822696; called by muse, mutect2, varscan2
- PEF1 | c.145C>T p.P49S | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV101035789; called by muse, mutect2, varscan2
- PEG3 | c.1435C>T p.L479F | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV55625621, COSV55635870; called by muse, mutect2, varscan2
- PGBD4 | c.1573C>T p.P525S | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.532); catalogued as COSV56626540; called by muse, mutect2, varscan2
- PHLDB1 | c.1484G>A p.W495* | Nonsense Mutation (SNP) | VAF 20/27 reads (74%) | catalogued as COSV61876545; called by muse, mutect2, varscan2
- PI4KA | c.1288C>T p.P430S | Missense Mutation (SNP) | VAF 48/83 reads (58%) | SIFT tolerated (0.34); PolyPhen benign (0.218); catalogued as rs754372202, COSV99744683; called by muse, mutect2, varscan2
- PIK3CA | c.2209G>A p.E737K | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.338); catalogued as COSV55884303; called by muse, mutect2, varscan2
- PIK3CB | c.2908C>T p.Q970* | Nonsense Mutation (SNP) | VAF 139/401 reads (35%) | catalogued as COSV56683557; called by muse, mutect2, varscan2
- PIP5K1C | c.1789G>A p.V597M | Missense Mutation (SNP) | VAF 43/73 reads (59%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.001); catalogued as COSV58950287; called by muse, mutect2, varscan2
- PIWIL2 | c.362G>T p.W121L | Missense Mutation (SNP) | VAF 33/152 reads (22%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as COSV63249884; called by muse, mutect2, varscan2
- PIWIL2 | c.2796G>A p.W932* | Nonsense Mutation (SNP) | VAF 27/75 reads (36%) | catalogued as COSV63249889; called by muse, mutect2, varscan2
- PKDCC | c.1399C>T p.R467W | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1480965660, COSV54305862; called by muse, mutect2, varscan2
- PKHD1L1 | c.5420T>C p.V1807A | Missense Mutation (SNP) | VAF 59/157 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs993825340, COSV65737749; called by muse, mutect2, varscan2
- PKHD1L1 | c.12379C>T p.L4127F | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV65737760; called by muse, mutect2, varscan2
- PKN3 | c.836G>A p.G279E | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV52574948; called by muse, mutect2, varscan2
982 further variants in this file (400 protein-altering or splice-affecting, 536 silent, 46 other) are not listed here.
